Somatic mutation profile of tumor specimen TCGA-EE-A29D-06A (aliquot TCGA-EE-A29D-06A-11D-A197-08) from TCGA case TCGA-EE-A29D, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 87.3 years (31,876 days).
Specimen TCGA-EE-A29D-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3100163a-f85a-4572-af6c-e55efd97bc99.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EE-A29D-10A (Blood Derived Normal), aliquot TCGA-EE-A29D-10A-01D-A199-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8a3fb344-1cec-40e2-bde6-b5916c8cf40c

The open-access MAF lists 4,587 somatic variants for this specimen: 2,896 protein-altering or splice-affecting, 1,565 silent, 126 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 2,641, Silent 1,565, Nonsense Mutation 175, RNA 51, Intron 43, Splice Region 30, Splice Site 26, 3'UTR 13, Frame Shift Del 11, 5'Flank 9, 3'Flank 6, Translation Start Site 5.

Variants (750 of 4,587; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCC6 | c.2420G>A p.R807Q | Missense Mutation (SNP) | VAF 23/59 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as rs72653794, CM053078, COSV52741966; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- CAPN3 | c.2381-2A>G p.X794_splice | Splice Site (SNP) | VAF 18/111 reads (16%) | catalogued as rs863224962, CS129341, COSV55522253; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- CNGA1 | c.1258C>T p.R420* | Nonsense Mutation (SNP) | VAF 36/108 reads (33%) | catalogued as rs369717052, CM1511726, COSV62057121; ClinVar: pathogenic; called by muse, varscan2
- GBA | c.1319C>T p.P440L | Missense Mutation (SNP) | VAF 31/48 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs74598136, CM990683, COSV59171139; ClinVar: pathogenic; called by muse, mutect2, varscan2
- KIT | c.1669T>C p.W557R | Missense Mutation (SNP) | VAF 84/114 reads (74%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs121913235, CM005329, COSV55386440, COSV55387014, COSV55389479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- KIT | c.2465A>T p.N822I | Missense Mutation (SNP) | VAF 203/208 reads (98%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs993022333, CM114977, COSV55406976, COSV55413741; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- MYH7 | c.4238C>T p.S1413L | Missense Mutation (SNP) | VAF 37/87 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs730880796, COSV62524224; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PROS1 | c.1543C>T p.R515C | Missense Mutation (SNP) | VAF 32/117 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as rs199469500, CM961188, COSV67776876; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- SFRP4 | c.694C>T p.R232* | Nonsense Mutation (SNP) | VAF 24/181 reads (13%) | catalogued as rs755007671, COSV71412681; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TGFBRAP1 | c.2471C>T p.P824L | Missense Mutation (SNP) | VAF 22/81 reads (27%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.654); catalogued as COSV51512596; called by muse, mutect2, varscan2
- A1CF | c.973G>A p.G325R | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT tolerated (0.16); PolyPhen benign (0.03); catalogued as rs1283329728, COSV50961498; called by muse, mutect2, varscan2
- A1CF | c.100G>A p.E34K | Missense Mutation (SNP) | VAF 17/55 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.218); catalogued as COSV50957343, COSV51028098; called by muse, mutect2, varscan2
- A2ML1 | c.2116G>A p.G706S | Missense Mutation (SNP) | VAF 19/84 reads (23%) | SIFT tolerated (0.52); PolyPhen benign (0.031); catalogued as COSV55298983; called by muse, mutect2, varscan2
- AATK | c.4076C>T p.S1359F (on ENST00000326724 / NM_001080395.3; = p.S1256F on NM_004920.2) | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.831); catalogued as COSV58373440; called by muse, mutect2
- ABCA12 | c.6998T>C p.V2333A (on ENST00000272895 / NM_173076.3; = p.V2015A on NM_015657.3) | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.314); catalogued as COSV55976548; called by muse, mutect2, varscan2
- ABCA12 | c.1632C>A p.N544K (on ENST00000272895 / NM_173076.3; = p.N226K on NM_015657.3) | Missense Mutation (SNP) | VAF 22/41 reads (54%) | SIFT tolerated (0.78); PolyPhen benign (0.001); catalogued as COSV55976587; called by muse, mutect2, varscan2
- ABCA12 | c.1211G>A p.R404Q (on ENST00000272895 / NM_173076.3; = p.R86Q on NM_015657.3) | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT tolerated (0.73); PolyPhen benign (0); catalogued as rs752328328, COSV55961290, COSV99789386; called by muse, mutect2, varscan2
- ABCA13 | c.10510C>T p.P3504S | Missense Mutation (SNP) | VAF 40/97 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV71294989; called by muse, mutect2, varscan2
- ABCA13 | c.14666C>T p.P4889L | Missense Mutation (SNP) | VAF 74/189 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV68950963; called by muse, mutect2, varscan2
- ABCA2 | c.6706G>A p.A2236T (on ENST00000614293; = p.A2206T on NM_001606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/22 reads (50%) | SIFT deleterious (0.02); PolyPhen benign (0.258); catalogued as COSV55806999; called by muse, mutect2, varscan2
- ABCA4 | c.580G>A p.G194R | Missense Mutation (SNP) | VAF 11/14 reads (79%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.931); catalogued as COSV64678409; called by muse, mutect2, varscan2
- ABCA6 | c.1159C>T p.P387S | Missense Mutation (SNP) | VAF 18/57 reads (32%) | SIFT tolerated (0.48); PolyPhen benign (0.041); catalogued as rs751228740, COSV52641384; called by muse, mutect2, varscan2
- ABCA6 | c.737G>A p.R246K | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT tolerated (0.39); PolyPhen benign (0.268); catalogued as rs1031845895, COSV52637397, COSV52637557, COSV52641215; called by mutect2, varscan2
- ABCB1 | c.2087C>T p.S696F | Missense Mutation (SNP) | VAF 35/87 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55947943; called by muse, mutect2, varscan2
- ABCB1 | c.356G>A p.S119N | Missense Mutation (SNP) | VAF 26/60 reads (43%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.598); catalogued as rs1428844378, COSV55964279; called by muse, mutect2, varscan2
- ABCB11 | c.3806C>T p.T1269I | Missense Mutation (SNP) | VAF 27/48 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99793268; called by muse, mutect2, varscan2
- ABCB11 | c.3613C>T p.P1205S | Missense Mutation (SNP) | VAF 38/144 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs1403850332, COSV55601803; called by muse, mutect2, varscan2
- ABCB11 | c.3404G>A p.G1135E | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1559179021, COSV55585434; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ABCB11 | c.1933G>A p.E645K | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT tolerated (0.58); PolyPhen benign (0.005); catalogued as COSV55601837; called by muse, mutect2, varscan2
- ABCB11 | c.1489C>T p.Q497* | Nonsense Mutation (SNP) | VAF 6/34 reads (18%) | catalogued as rs267598993, COSV55594212; called by mutect2, varscan2
- ABCB5 | c.1558G>A p.E520K (on ENST00000404938 / NM_001163941.2; = p.E75K on NM_178559.6) | Missense Mutation (SNP) | VAF 52/67 reads (78%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.89); catalogued as COSV51721154; called by muse, mutect2, varscan2
- ABCB5 | c.2261G>A p.G754E (on ENST00000404938 / NM_001163941.2; = p.G309E on NM_178559.6) | Missense Mutation (SNP) | VAF 23/106 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV51721184; called by muse, mutect2
- ABCB5 | c.2440G>A p.G814S (on ENST00000404938 / NM_001163941.2; = p.G369S on NM_178559.6) | Missense Mutation (SNP) | VAF 13/120 reads (11%) | SIFT tolerated (0.05); PolyPhen probably damaging (1); catalogued as rs139378066; called by muse, mutect2, varscan2
- ABCB5 | c.3559G>A p.D1187N (on ENST00000404938 / NM_001163941.2; = p.D742N on NM_178559.6) | Missense Mutation (SNP) | VAF 37/132 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.668); catalogued as rs759087816, COSV51703971; called by muse, mutect2, varscan2
- ABCC11 | c.3209C>T p.S1070F | Missense Mutation (SNP) | VAF 41/43 reads (95%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.966); catalogued as COSV62326041; called by muse, mutect2, varscan2
- ABCC11 | c.2413G>A p.V805I | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT tolerated (0.24); PolyPhen benign (0.013); catalogued as rs1424931821, COSV62326046; called by muse, mutect2, varscan2
- ABCC11 | c.1678G>A p.E560K | Missense Mutation (SNP) | VAF 18/45 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.971); catalogued as COSV62326052; called by muse, mutect2, varscan2
- ABCC12 | c.2776C>T p.H926Y | Missense Mutation (SNP) | VAF 18/65 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.065); catalogued as COSV60912522, COSV60917542; called by muse, mutect2, varscan2
- ABCC3 | c.1828G>A p.E610K | Missense Mutation (SNP) | VAF 38/84 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV53324526; called by muse, mutect2, varscan2
- ABCC8 | c.1381T>A p.L461I | Missense Mutation (SNP) | VAF 143/321 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.888); catalogued as COSV56858138; called by muse, varscan2
- ABCC9 | c.2785C>T p.Q929* | Nonsense Mutation (SNP) | VAF 28/64 reads (44%) | catalogued as COSV53987237; called by muse, mutect2, varscan2
- ABCD2 | c.931G>A p.G311R | Missense Mutation (SNP) | VAF 36/77 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1379602584, COSV100429833; called by muse, mutect2, varscan2
- ABCE1 | c.409C>T p.P137S | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.513); catalogued as rs755429648, COSV99668682; called by muse, mutect2, varscan2
- ABCG4 | c.1760G>A p.R587Q | Missense Mutation (SNP) | VAF 13/14 reads (93%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs764693748, COSV56645862; called by muse, mutect2, varscan2
- ABCG5 | c.839T>G p.M280R | Missense Mutation (SNP) | VAF 245/320 reads (77%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV53213680; called by muse, mutect2, varscan2
- ABCG8 | c.1567C>T p.P523S | Missense Mutation (SNP) | VAF 122/909 reads (13%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.455); catalogued as COSV55397044; called by muse, mutect2, varscan2
- ABLIM2 | c.1229C>T p.P410L (on ENST00000341937 / NM_001130084.2; = p.P443L on NM_001130083.2) | Missense Mutation (SNP) | VAF 14/26 reads (54%) | SIFT deleterious (0); PolyPhen benign (0.097); catalogued as rs546789510, COSV99590618; called by muse, mutect2
- ABLIM2 | c.1228C>T p.P410S (on ENST00000341937 / NM_001130084.2; = p.P443S on NM_001130083.2) | Missense Mutation (SNP) | VAF 12/24 reads (50%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as COSV99589776; called by muse, mutect2, varscan2
- ABRA | c.13G>A p.E5K | Missense Mutation (SNP) | VAF 29/75 reads (39%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.186); catalogued as rs780637593, COSV61731924; called by muse, mutect2, varscan2
- ACACB | c.1913C>T p.P638L | Missense Mutation (SNP) | VAF 9/57 reads (16%) | SIFT tolerated (0.12); PolyPhen benign (0.033); catalogued as COSV58140477; called by muse, mutect2, varscan2
- ACAP3 | c.858G>A p.W286* | Nonsense Mutation (SNP) | VAF 15/38 reads (39%) | catalogued as COSV61223683; called by muse, mutect2, varscan2
- ACER1 | c.344G>A p.G115E | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT tolerated (0.79); PolyPhen benign (0.005); catalogued as rs866874353, COSV56836966; called by muse, mutect2, varscan2
- ACKR3 | c.226G>A p.G76S | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.927); catalogued as COSV56021976, COSV99799531; called by muse, mutect2, varscan2
- ACO1 | c.113C>T p.S38L | Missense Mutation (SNP) | VAF 33/41 reads (80%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs537741206, COSV59385166; called by muse, mutect2, varscan2
- ACOT11 | c.136G>A p.E46K | Missense Mutation (SNP) | VAF 22/28 reads (79%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.915); catalogued as rs766706122, COSV59352042; called by muse, mutect2, varscan2
- ACOT12 | c.1057G>A p.D353N | Missense Mutation (SNP) | VAF 34/67 reads (51%) | SIFT tolerated (0.25); PolyPhen benign (0.001); catalogued as COSV56898346; called by muse, mutect2, varscan2
- ACOXL | c.709C>T p.P237S | Missense Mutation (SNP) | VAF 17/70 reads (24%) | SIFT tolerated (0.47); PolyPhen benign (0.001); catalogued as COSV61331155; called by muse, mutect2, varscan2
- ACP3 | c.133G>A p.G45R | Missense Mutation (SNP) | VAF 15/67 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60488758; called by muse, mutect2, varscan2
- ACP6 | c.502C>T p.R168W | Missense Mutation (SNP) | VAF 26/190 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs978886014, COSV65076275; called by muse, mutect2
- ACSL3 | c.148G>T p.E50* | Nonsense Mutation (SNP) | VAF 16/47 reads (34%) | catalogued as COSV62484848; called by muse, varscan2
- ACSM2B | c.1013G>A p.G338E | Missense Mutation (SNP) | VAF 44/155 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100312781; called by muse, mutect2, varscan2
- ACSM2B | c.188G>A p.R63Q | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.861); catalogued as rs757950871, COSV61656530; called by muse, mutect2, varscan2
- ACSM3 | c.1435G>A p.D479N | Missense Mutation (SNP) | VAF 59/108 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1343740989, COSV55504291; called by muse, mutect2, varscan2
- ACTN1 | c.1385+1G>A p.X462_splice | Splice Site (SNP) | VAF 14/48 reads (29%) | catalogued as COSV51997973; called by muse, mutect2, varscan2
- ACTN2 | c.904C>T p.P302S | Missense Mutation (SNP) | VAF 56/149 reads (38%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.987); catalogued as COSV63976970; called by muse, mutect2, varscan2
- ADAD1 | c.1395G>A p.M465I | Missense Mutation (SNP) | VAF 54/170 reads (32%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as COSV56643538; called by muse, mutect2, varscan2
- ADAD2 | c.734-1G>A p.X245_splice (on ENST00000315906 / NM_001145400.2; = p.E327K on NM_139174.4) | Splice Site (SNP) | VAF 8/13 reads (62%) | catalogued as COSV51895415; called by muse, mutect2, varscan2
- ADAM11 | c.2167G>A p.E723K | Missense Mutation (SNP) | VAF 19/109 reads (17%) | SIFT tolerated (0.78); PolyPhen benign (0.017); catalogued as rs1222013499, COSV52350006; called by muse, mutect2, varscan2
- ADAM2 | c.1855G>A p.D619N | Missense Mutation (SNP) | VAF 32/107 reads (30%) | SIFT tolerated (0.09); PolyPhen benign (0.045); catalogued as COSV55868843; called by muse, varscan2
- ADAM22 | c.1559C>T p.S520L | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.616); catalogued as COSV99718470; called by muse, mutect2
- ADAM7 | c.905G>A p.G302E | Missense Mutation (SNP) | VAF 33/96 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51535001; called by muse, varscan2
- ADAM7 | c.1838G>A p.G613E | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT tolerated (0.23); PolyPhen benign (0.142); catalogued as COSV51542992; called by muse, mutect2, varscan2
- ADAM7 | c.1915G>A p.E639K | Missense Mutation (SNP) | VAF 21/43 reads (49%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.76); catalogued as rs1034941983, COSV51541580; called by muse, mutect2, varscan2
- ADAMTS10 | c.1217G>A p.G406E | Missense Mutation (SNP) | VAF 48/95 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs886881598, COSV54359717; called by muse, mutect2, varscan2
- ADAMTS12 | c.907G>A p.E303K | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.173); catalogued as COSV100710901, COSV61276249, COSV61280837; called by muse, mutect2, varscan2
- ADAMTS18 | c.2854C>A p.Q952K | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.656); catalogued as COSV51423359; called by muse, varscan2
- ADAMTS19 | c.1973G>A p.G658E | Missense Mutation (SNP) | VAF 31/170 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50807614; called by muse, mutect2, varscan2
- ADAMTS2 | c.3220G>A p.E1074K | Missense Mutation (SNP) | VAF 24/42 reads (57%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.793); catalogued as COSV52394552; called by muse, mutect2, varscan2
- ADAMTS2 | c.1460C>T p.S487F | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51106856; called by muse, mutect2
- ADAMTS4 | c.575C>T p.P192L | Missense Mutation (SNP) | VAF 123/174 reads (71%) | SIFT deleterious (0.02); PolyPhen benign (0.101); catalogued as COSV63488771; called by muse, mutect2, varscan2
- ADAMTS6 | c.2647C>T p.P883S | Missense Mutation (SNP) | VAF 19/39 reads (49%) | SIFT tolerated (0.27); PolyPhen benign (0.026); catalogued as COSV58685289; called by muse, mutect2, varscan2
- ADAMTS6 | c.1078G>A p.D360N | Missense Mutation (SNP) | VAF 16/34 reads (47%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.861); catalogued as COSV66858355; called by muse, varscan2
- ADAMTS9 | c.2909G>A p.G970E | Missense Mutation (SNP) | VAF 197/594 reads (33%) | SIFT tolerated (0.09); PolyPhen benign (0.274); catalogued as COSV55791162; called by muse, mutect2, varscan2
- ADCY7 | c.1550G>A p.R517Q | Missense Mutation (SNP) | VAF 23/30 reads (77%) | SIFT tolerated (0.43); PolyPhen benign (0.026); catalogued as rs1023797221, COSV54265741; called by muse, mutect2, varscan2
- ADD3 | c.1802C>T p.P601L | Missense Mutation (SNP) | VAF 28/48 reads (58%) | SIFT tolerated (0.07); PolyPhen benign (0.051); catalogued as rs139595633; called by muse, mutect2
- ADGRB2 | c.2795C>T p.P932L | Missense Mutation (SNP) | VAF 15/21 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57079190; called by muse, mutect2, varscan2
- ADGRB2 | c.1295C>T p.S432F | Missense Mutation (SNP) | VAF 25/52 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57079202; called by muse, mutect2, varscan2
- ADGRE3 | c.1057G>A p.D353N | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.893); catalogued as COSV53735153; called by muse, mutect2, varscan2
- ADGRE3 | c.920G>A p.W307* | Nonsense Mutation (SNP) | VAF 43/80 reads (54%) | catalogued as COSV53728781; called by muse, mutect2, varscan2
- ADGRE5 | c.1003G>T p.E335* (on ENST00000242786 / NM_078481.4; = p.E242* on NM_001784.5) | Nonsense Mutation (SNP) | VAF 23/52 reads (44%) | catalogued as COSV99663320; called by muse, mutect2, varscan2
- ADGRF1 | c.344C>T p.S115L | Missense Mutation (SNP) | VAF 32/62 reads (52%) | SIFT tolerated (0.12); PolyPhen benign (0.11); catalogued as COSV64801238; called by muse, mutect2, varscan2
- ADGRF5 | c.3010C>T p.P1004S | Missense Mutation (SNP) | VAF 13/88 reads (15%) | SIFT tolerated (0.23); PolyPhen benign (0.065); catalogued as COSV51930512, COSV51930891; called by muse, varscan2
- ADGRG1 | c.1292C>T p.P431L | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV101113578; called by muse, mutect2, varscan2
- ADGRG4 | c.3976G>A p.G1326R | Missense Mutation (SNP) | VAF 49/58 reads (84%) | SIFT tolerated (0.56); PolyPhen benign (0.007); catalogued as COSV54963390; called by muse, mutect2, varscan2
- ADGRG4 | c.6580C>T p.P2194S | Missense Mutation (SNP) | VAF 76/82 reads (93%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.992); catalogued as COSV54967263; called by muse, mutect2, varscan2
- ADGRG5 | c.1399G>A p.G467R | Missense Mutation (SNP) | VAF 9/19 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100446348, COSV61084653; called by muse, mutect2, varscan2
- ADGRG6 | c.10C>T p.R4C | Missense Mutation (SNP) | VAF 8/15 reads (53%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.17); catalogued as rs756333358, COSV51598734; called by muse, mutect2, varscan2
- ADGRL1 | c.1066G>A p.E356K (on ENST00000340736 / NM_001008701.3; = p.E351K on NM_014921.5) | Missense Mutation (SNP) | VAF 35/71 reads (49%) | SIFT tolerated (0.52); PolyPhen possibly damaging (0.826); catalogued as COSV61566783; called by muse, mutect2, varscan2
- ADGRL3 | c.2525C>T p.S842F (on ENST00000506720 / NM_001322402.2; = p.S774F on NM_015236.6) | Missense Mutation (SNP) | VAF 162/177 reads (92%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV72231375, COSV72232019; called by muse, mutect2, varscan2
- ADGRV1 | c.2924C>T p.T975I | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT tolerated (0.22); PolyPhen benign (0.013); catalogued as COSV67995129; called by muse, mutect2, varscan2
- ADGRV1 | c.4555G>A p.G1519R | Missense Mutation (SNP) | VAF 25/80 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV67979912; called by muse, mutect2, varscan2
- ADGRV1 | c.12545G>A p.G4182E | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.245); catalogued as rs794727821, COSV67995908; called by muse, mutect2, varscan2
- ADGRV1 | c.16757G>A p.G5586E | Missense Mutation (SNP) | VAF 33/139 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.018); catalogued as COSV67995912; called by muse, mutect2, varscan2
- ADH1C | c.376G>A p.D126N | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); catalogued as COSV72463424; called by muse, mutect2, varscan2
- ADH6 | c.139T>G p.C47G | Missense Mutation (SNP) | VAF 34/110 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52958340; called by muse, mutect2, varscan2
- ADORA3 | c.613C>T p.R205W | Missense Mutation (SNP) | VAF 26/28 reads (93%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.999); catalogued as rs557748857, COSV53985808; called by muse, mutect2, varscan2
- ADORA3 | c.55G>A p.E19K | Missense Mutation (SNP) | VAF 10/18 reads (56%) | SIFT deleterious (0); PolyPhen possibly damaging (0.765); catalogued as COSV53987022; called by muse, mutect2, varscan2
- ADPRHL1 | c.514G>A p.G172S | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV62910981; called by muse, mutect2
- ADPRS | c.683C>T p.S228F | Missense Mutation (SNP) | VAF 17/20 reads (85%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.899); catalogued as COSV99255643; called by muse, mutect2, varscan2
- AFF2 | c.3805G>A p.E1269K | Missense Mutation (SNP) | VAF 65/67 reads (97%) | SIFT deleterious (0); PolyPhen possibly damaging (0.57); catalogued as COSV54008651, COSV99662654; called by muse, mutect2, varscan2
- AFF4 | c.2249G>A p.R750K | Missense Mutation (SNP) | VAF 86/118 reads (73%) | SIFT tolerated (0.34); PolyPhen benign (0.001); catalogued as COSV54800089; called by muse, mutect2, varscan2
- AGTR1 | c.938T>G p.F313C | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT deleterious (0.04); PolyPhen benign (0.01); catalogued as COSV62560279; called by muse, mutect2, varscan2
- AHDC1 | c.679C>T p.P227S | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.027); catalogued as COSV55942540; called by muse, mutect2, varscan2
- AHI1 | c.214C>T p.P72S | Missense Mutation (SNP) | VAF 44/108 reads (41%) | SIFT tolerated (0.38); PolyPhen benign (0.003); catalogued as COSV55636641; called by muse, mutect2, varscan2
- AHNAK | c.17255C>T p.S5752F | Missense Mutation (SNP) | VAF 50/91 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV57231582; called by muse, mutect2, varscan2
- AHNAK | c.14677G>A p.E4893K | Missense Mutation (SNP) | VAF 23/48 reads (48%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.885); catalogued as rs748877920, COSV57227711, COSV57231599; called by muse, mutect2, varscan2
- AHNAK | c.13973C>T p.P4658L | Missense Mutation (SNP) | VAF 77/351 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57231619; called by muse, mutect2, varscan2
- AHNAK | c.12806C>T p.P4269L | Missense Mutation (SNP) | VAF 107/241 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs765211544, COSV57231633; called by muse, mutect2, varscan2
- AHNAK2 | c.13630G>A p.G4544R | Missense Mutation (SNP) | VAF 44/228 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV60931626; called by muse, varscan2
- AHNAK2 | c.6572C>T p.S2191F | Missense Mutation (SNP) | VAF 44/209 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV60931641; called by muse, mutect2, varscan2
- AHNAK2 | c.3754C>T p.P1252S | Missense Mutation (SNP) | VAF 99/200 reads (50%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.982); catalogued as COSV60931652; called by muse, mutect2, varscan2
- AIMP1 | c.739C>T p.P247S | Missense Mutation (SNP) | VAF 56/152 reads (37%) | SIFT tolerated (0.07); PolyPhen benign (0.382); catalogued as rs748529660, COSV63638017, COSV63639610; called by muse, mutect2, varscan2
- AIP | c.673C>T p.Q225* | Nonsense Mutation (SNP) | VAF 12/36 reads (33%) | catalogued as COSV99653861; called by muse, mutect2, varscan2
- AK7 | c.1249G>A p.D417N | Missense Mutation (SNP) | VAF 19/58 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.052); catalogued as rs111905580, COSV50875933; called by muse, mutect2, varscan2
- AK9 | c.5065G>A p.E1689K | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); catalogued as COSV69853480; called by muse, mutect2, varscan2
- AKAP11 | c.2230C>T p.P744S | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT tolerated (0.31); PolyPhen benign (0.147); catalogued as COSV50303036; called by muse, mutect2, varscan2
- AKAP11 | c.5191G>C p.D1731H | Missense Mutation (SNP) | VAF 18/61 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50303078; called by muse, mutect2, varscan2
- AKAP3 | c.1592C>T p.A531V | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99962665; called by muse, mutect2, varscan2
- AKAP4 | c.319C>T p.P107S | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT deleterious (0.03); PolyPhen benign (0.08); catalogued as rs139891326, COSV100654380; called by muse, mutect2, varscan2
- AKAP9 | c.4208G>A p.G1403E | Missense Mutation (SNP) | VAF 27/81 reads (33%) | SIFT tolerated (0.53); PolyPhen benign (0.014); catalogued as COSV62358554; called by muse, mutect2, varscan2
- AKNAD1 | c.418G>A p.D140N | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.95); catalogued as rs376781127; called by muse, mutect2, varscan2
- AKR1C4 | c.793G>A p.V265I | Missense Mutation (SNP) | VAF 34/81 reads (42%) | SIFT tolerated (0.2); PolyPhen benign (0.105); catalogued as COSV54125732; called by muse, mutect2, varscan2
- AKT2 | c.1052del p.Y351Sfs*224 | Frame Shift Del (DEL) | VAF 79/473 reads (17%) | catalogued as COSV60908487; called by mutect2, pindel, varscan2
- AL669918.1 | c.2120C>T p.A707V | Missense Mutation (SNP) | VAF 45/86 reads (52%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.048); catalogued as rs752350484, COSV71271014; called by muse, mutect2, varscan2
- ALB | c.67C>T p.R23C | Missense Mutation (SNP) | VAF 64/111 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs80008208, CM900010, COSV55740986; ClinVar: other / uncertain significance; called by muse, mutect2, varscan2
- ALB | c.1300C>T p.R434C | Missense Mutation (SNP) | VAF 63/107 reads (59%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); catalogued as rs78575701, CM984718, COSV104405337, COSV55736801, COSV55738814; ClinVar: not provided; called by muse, mutect2, varscan2
- ALG3 | c.452C>T p.P151L | Missense Mutation (SNP) | VAF 3/14 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56614397; called by muse, mutect2
- ALK | c.2024C>T p.P675L | Missense Mutation (SNP) | VAF 108/131 reads (82%) | SIFT deleterious (0.02); PolyPhen benign (0.013); catalogued as COSV66590499; called by muse, mutect2, varscan2
- ALKAL1 | c.260C>T p.S87L | Missense Mutation (SNP) | VAF 31/69 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as rs763234408, COSV62130942; called by muse, mutect2, varscan2
- ALOX12B | c.547G>A p.G183R | Missense Mutation (SNP) | VAF 29/139 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV59876667; called by muse, mutect2, varscan2
- ALOX15B | c.754C>T p.R252C | Missense Mutation (SNP) | VAF 24/56 reads (43%) | SIFT tolerated (0.06); PolyPhen benign (0.226); catalogued as rs1247893584, COSV66480188; called by muse, mutect2, varscan2
- ALPK2 | c.6002C>T p.P2001L | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV64497457; called by muse, mutect2, varscan2
- ALPK2 | c.4960G>A p.A1654T | Missense Mutation (SNP) | VAF 31/65 reads (48%) | SIFT tolerated (0.09); PolyPhen benign (0.131); catalogued as COSV64497463; called by muse, mutect2, varscan2
- ALPK2 | c.503C>T p.S168F | Missense Mutation (SNP) | VAF 53/131 reads (40%) | SIFT tolerated (0.88); PolyPhen benign (0); catalogued as COSV64497473; called by muse, mutect2, varscan2
- ALPK3 | c.4543C>T p.P1515S | Missense Mutation (SNP) | VAF 18/119 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs193022517, COSV51940255; called by muse, mutect2, varscan2
- AMBN | c.1109G>A p.G370E | Missense Mutation (SNP) | VAF 12/90 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.974); catalogued as rs769911881, COSV59827155; called by muse, mutect2, varscan2
- AMIGO2 | c.341C>T p.S114F | Missense Mutation (SNP) | VAF 24/103 reads (23%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.478); catalogued as COSV56974676; called by muse, mutect2, varscan2
- AMPD3 | c.572C>T p.P191L (on ENST00000396553 / NM_001025389.2; = p.P200L on NM_000480.3) | Missense Mutation (SNP) | VAF 36/78 reads (46%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as rs752415155, COSV67332525; called by muse, mutect2, varscan2
- AMPD3 | c.877G>A p.E293K (on ENST00000396553 / NM_001025389.2; = p.E302K on NM_000480.3) | Missense Mutation (SNP) | VAF 64/146 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as rs760590808, COSV67331501; called by muse, mutect2, varscan2
- AMPD3 | c.1618A>G p.K540E (on ENST00000396553 / NM_001025389.2; = p.K549E on NM_000480.3) | Missense Mutation (SNP) | VAF 25/63 reads (40%) | SIFT tolerated (0.13); PolyPhen benign (0.327); catalogued as COSV67332534; called by muse, mutect2, varscan2
- AMTN | c.620G>A p.G207E | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.084); catalogued as COSV59489674; called by muse, mutect2, varscan2
- AMY2A | c.161G>A p.G54E | Missense Mutation (SNP) | VAF 116/141 reads (82%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs148925092; called by muse, mutect2, varscan2
- ANAPC5 | c.1492C>T p.P498S | Missense Mutation (SNP) | VAF 71/322 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.922); catalogued as COSV55845526; called by muse, mutect2, varscan2
- ANGPTL3 | c.956A>T p.K319M | Missense Mutation (SNP) | VAF 23/28 reads (82%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV52021958; called by muse, mutect2, varscan2
- ANK1 | c.3457C>T p.P1153S | Missense Mutation (SNP) | VAF 24/42 reads (57%) | SIFT deleterious (0.01); PolyPhen benign (0.244); catalogued as rs773805000, COSV55896539; called by muse, mutect2, varscan2
- ANK2 | c.263C>T p.S88F | Missense Mutation (SNP) | VAF 13/81 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV52189910; called by muse, mutect2, varscan2
- ANK2 | c.7613C>T p.P2538L | Missense Mutation (SNP) | VAF 28/166 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV100000296, COSV52189929; called by muse, mutect2, varscan2
- ANK2 | c.11165C>T p.S3722F | Missense Mutation (SNP) | VAF 53/104 reads (51%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.957); catalogued as COSV52189945; called by muse, mutect2, varscan2
- ANK3 | c.8078G>A p.G2693E | Missense Mutation (SNP) | VAF 60/94 reads (64%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0); catalogued as COSV55083249; called by muse, mutect2, varscan2
- ANK3 | c.6658C>T p.Q2220* | Nonsense Mutation (SNP) | VAF 74/113 reads (65%) | catalogued as COSV55083277; called by muse, mutect2, varscan2
- ANK3 | c.6184G>A p.E2062K | Missense Mutation (SNP) | VAF 23/79 reads (29%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.985); catalogued as COSV55083305; called by muse, mutect2, varscan2
- ANK3 | c.4652C>T p.S1551F | Missense Mutation (SNP) | VAF 31/121 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.897); catalogued as COSV55083317; called by muse, mutect2, varscan2
- ANKRD20A2P | c.131G>A p.G44D | Missense Mutation (SNP) | VAF 26/84 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV66465091; called by muse, mutect2, varscan2
- ANKRD30A | c.646G>A p.G216R (on ENST00000611781; = p.G160R on NM_052997.2) | Missense Mutation (SNP) | VAF 34/176 reads (19%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.995); catalogued as COSV64621992; called by muse, mutect2, varscan2
- ANKRD30A | c.2839G>A p.E947K (on ENST00000611781; = p.E891K on NM_052997.2) | Missense Mutation (SNP) | VAF 20/105 reads (19%) | SIFT tolerated (0.72); PolyPhen benign (0.01); catalogued as rs371663598, COSV64603807; called by muse, mutect2, varscan2
- ANKRD30A | c.3289G>A p.E1097K (on ENST00000611781; = p.E1041K on NM_052997.2) | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.899); catalogued as COSV64622023; called by muse, mutect2, varscan2
- ANKRD30A | c.3496G>T p.G1166W (on ENST00000611781; = p.G1110W on NM_052997.2) | Missense Mutation (SNP) | VAF 47/198 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.956); catalogued as COSV64622032; called by muse, mutect2, varscan2
- ANKRD34B | c.1331C>G p.T444S | Missense Mutation (SNP) | VAF 44/68 reads (65%) | SIFT tolerated (0.05); PolyPhen benign (0.01); catalogued as COSV58614561; called by muse, mutect2, varscan2
- ANKRD55 | c.1825C>T p.P609S | Missense Mutation (SNP) | VAF 44/88 reads (50%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0); catalogued as rs777716135, COSV61950965; called by muse, mutect2, varscan2
- ANKRD55 | c.1345G>A p.A449T | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.007); catalogued as COSV61950970; called by muse, mutect2, varscan2
- ANKS1B | c.1099G>A p.E367K | Missense Mutation (SNP) | VAF 30/36 reads (83%) | SIFT deleterious (0.01); PolyPhen benign (0.054); catalogued as COSV61377694; called by muse, mutect2, varscan2
- ANKS4B | c.851C>T p.P284L | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as rs1202676259, COSV61140375; called by muse, mutect2, varscan2
- ANO4 | c.827G>A p.G276E (on ENST00000392977 / NM_001286615.2; = p.G241E on NM_178826.4) | Missense Mutation (SNP) | VAF 13/14 reads (93%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.974); catalogued as COSV54612988; called by muse, mutect2, varscan2
- ANO4 | c.2276C>T p.P759L (on ENST00000392977 / NM_001286615.2; = p.P724L on NM_178826.4) | Missense Mutation (SNP) | VAF 31/35 reads (89%) | SIFT tolerated (0.05); PolyPhen probably damaging (1); catalogued as COSV54614445; called by muse, mutect2, varscan2
- ANO9 | c.550G>A p.G184R | Missense Mutation (SNP) | VAF 21/45 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV60452015; called by muse, mutect2, varscan2
- ANP32A | c.124G>T p.E42* | Nonsense Mutation (SNP) | VAF 83/140 reads (59%) | catalogued as COSV51189965; called by muse, mutect2, varscan2
- ANXA4 | c.427C>T p.R143C | Missense Mutation (SNP) | VAF 13/109 reads (12%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as rs755577388, COSV67848315; called by muse, mutect2, varscan2
- AOC1 | c.1252C>T p.L418F | Missense Mutation (SNP) | VAF 17/60 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.362); catalogued as COSV62870930; called by muse, mutect2, varscan2
- AP2A1 | c.2801C>T p.T934I | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs770250621, COSV58243108; called by muse, mutect2
- APCDD1 | c.443A>T p.H148L | Missense Mutation (SNP) | VAF 45/50 reads (90%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.462); catalogued as COSV100790022; called by muse, mutect2, varscan2
- APEH | c.1906C>T p.P636S | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT tolerated (0.41); PolyPhen benign (0.003); catalogued as COSV56536951; called by muse, mutect2, varscan2
- APLP1 | c.601C>T p.R201W | Missense Mutation (SNP) | VAF 17/89 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs758414613, COSV55707101; called by muse, mutect2, varscan2
- APOB | c.12811G>A p.E4271K | Missense Mutation (SNP) | VAF 537/745 reads (72%) | SIFT tolerated (0.72); PolyPhen benign (0.001); catalogued as COSV51953666; called by muse, mutect2, varscan2
- APOB | c.12706C>T p.H4236Y | Missense Mutation (SNP) | VAF 568/775 reads (73%) | SIFT tolerated (0.8); PolyPhen benign (0.006); catalogued as COSV51932580; called by muse, mutect2, varscan2
- APOB | c.9881C>T p.S3294L | Missense Mutation (SNP) | VAF 129/817 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV51953681, COSV99267533; called by muse, mutect2, varscan2
- APOB | c.9665C>T p.S3222F | Missense Mutation (SNP) | VAF 270/673 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.635); catalogued as COSV51953688; called by muse, mutect2, varscan2
- APOB | c.8787G>A p.W2929* | Nonsense Mutation (SNP) | VAF 176/1036 reads (17%) | catalogued as rs1340673456, COSV51953708; called by muse, mutect2, varscan2
- APOB | c.7928C>T p.S2643F | Missense Mutation (SNP) | VAF 128/741 reads (17%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.606); catalogued as COSV51953728; called by muse, mutect2, varscan2
- APOB | c.409G>A p.E137K | Missense Mutation (SNP) | VAF 283/631 reads (45%) | SIFT tolerated (0.28); PolyPhen benign (0.015); catalogued as COSV51946797; called by muse, mutect2, varscan2
- APOC1 | c.229G>A p.E77K | Missense Mutation (SNP) | VAF 183/428 reads (43%) | SIFT tolerated (0.05); PolyPhen benign (0.021); catalogued as COSV52992352; called by muse, mutect2, varscan2
- APOC4-APOC2 | c.5C>T p.S2F | Missense Mutation (SNP) | VAF 77/172 reads (45%) | SIFT deleterious, low confidence (0.03); catalogued as COSV52990990; called by muse, mutect2, varscan2
- APP | c.850G>A p.E284K | Missense Mutation (SNP) | VAF 18/38 reads (47%) | SIFT tolerated (0.35); PolyPhen benign (0.292); catalogued as COSV61005246; called by muse, mutect2, varscan2
- AQP2 | c.13C>T p.R5C | Missense Mutation (SNP) | VAF 34/74 reads (46%) | SIFT tolerated (0.1); PolyPhen benign (0.006); catalogued as rs772585705, COSV52232066; called by muse, mutect2
- AQP2 | c.738G>A p.W246* | Nonsense Mutation (SNP) | VAF 15/24 reads (63%) | catalogued as COSV52230597; called by muse, mutect2, varscan2
- ARAP2 | c.4883G>A p.R1628Q | Missense Mutation (SNP) | VAF 29/80 reads (36%) | SIFT tolerated (0.2); PolyPhen benign (0.223); catalogued as rs771641324, COSV58281935, COSV58289114; called by muse, mutect2, varscan2
- ARAP2 | c.4333G>A p.E1445K | Missense Mutation (SNP) | VAF 24/63 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as COSV58292794; called by muse, mutect2, varscan2
- ARAP2 | c.3768C>G p.I1256M | Missense Mutation (SNP) | VAF 16/30 reads (53%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.99); catalogued as COSV58292802; called by muse, mutect2, varscan2
- AREG | c.713G>A p.R238Q | Missense Mutation (SNP) | VAF 29/87 reads (33%) | SIFT tolerated (0.11); PolyPhen benign (0.021); catalogued as rs1219113338; called by muse, mutect2, varscan2
- ARFGEF1 | c.2521C>T p.P841S | Missense Mutation (SNP) | VAF 92/129 reads (71%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.993); catalogued as COSV51617390; called by muse, mutect2, varscan2
- ARHGAP12 | c.1907G>A p.R636Q | Missense Mutation (SNP) | VAF 15/82 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.876); catalogued as rs146011999, COSV60962777; called by muse, mutect2, varscan2
- ARHGAP33 | c.629G>A p.G210E | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); catalogued as COSV50169995; called by muse, mutect2
- ARHGAP35 | c.4472C>T p.S1491F | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0); catalogued as COSV68335864; called by muse, mutect2, varscan2
- ARHGAP44 | c.608G>A p.S203N | Missense Mutation (SNP) | VAF 15/62 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.03); catalogued as COSV52393594, COSV52403325; called by muse, mutect2, varscan2
- ARHGAP45 | c.1915G>A p.D639N | Missense Mutation (SNP) | VAF 18/41 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.173); catalogued as rs751999074, COSV57436666; called by muse, mutect2, varscan2
- ARHGAP5 | c.3005C>A p.P1002Q | Missense Mutation (SNP) | VAF 55/117 reads (47%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.798); catalogued as COSV61539436; called by muse, mutect2, varscan2
- ARHGEF17 | c.1450G>A p.E484K | Missense Mutation (SNP) | VAF 26/59 reads (44%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.549); catalogued as COSV55238516; called by muse, mutect2, varscan2
- ARHGEF17 | c.4088-1G>A p.X1363_splice | Splice Site (SNP) | VAF 8/57 reads (14%) | catalogued as COSV55238525; called by muse, mutect2, varscan2
- ARID1B | c.5750C>T p.P1917L | Missense Mutation (SNP) | VAF 39/85 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV51681987; called by muse, mutect2, varscan2
- ARID4A | c.998C>T p.P333L | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.608); catalogued as COSV62166811; called by muse, mutect2
- ARMC3 | c.1817G>A p.S606N | Missense Mutation (SNP) | VAF 31/146 reads (21%) | SIFT tolerated (0.16); PolyPhen benign (0.001); catalogued as rs916129043, COSV53063288, COSV53068108; called by muse, mutect2, varscan2
- ARMC4 | c.2496G>A p.M832I | Missense Mutation (SNP) | VAF 29/69 reads (42%) | SIFT tolerated (0.22); PolyPhen benign (0.015); catalogued as COSV59458393; called by muse, mutect2, varscan2
- ARMC4 | c.638G>A p.G213E | Missense Mutation (SNP) | VAF 72/155 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs750082472, COSV53464135; called by muse, mutect2, varscan2
- ARPP21 | c.1262C>T p.S421L | Missense Mutation (SNP) | VAF 15/73 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.198); catalogued as rs1356078676, COSV51804101; called by muse, mutect2, varscan2
- ASAH2 | c.1573C>T p.Q525* | Nonsense Mutation (SNP) | VAF 14/47 reads (30%) | catalogued as rs1156604701; called by muse, mutect2, varscan2
- ASAP2 | c.2897C>T p.S966F | Missense Mutation (SNP) | VAF 17/91 reads (19%) | SIFT tolerated (0.74); PolyPhen benign (0.069); catalogued as rs762610686, COSV53007212; called by muse, mutect2, varscan2
- ASB12 | c.661C>T p.P221S | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as COSV62857818; called by muse, mutect2
- ASCC1 | c.850C>T p.R284* (on ENST00000342444 / NM_001369085.1; = p.R256* on NM_001198798.2 and 8 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 10/44 reads (23%) | catalogued as rs141611243, COSV57729156; called by mutect2, varscan2
- ASH1L | c.8173C>T p.P2725S (on ENST00000368346 / NM_001366177.2; = p.P2720S on NM_018489.3) | Missense Mutation (SNP) | VAF 49/91 reads (54%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV64214187; called by muse, mutect2, varscan2
- ASIC1 | c.496C>T p.R166* | Nonsense Mutation (SNP) | VAF 36/71 reads (51%) | catalogued as rs1362476233, COSV57319990; called by muse, mutect2, varscan2
- ASTN2 | c.1520C>T p.S507F (on ENST00000313400 / NM_001365069.1; = p.S456F on NM_014010.5) | Missense Mutation (SNP) | VAF 19/35 reads (54%) | SIFT deleterious (0); PolyPhen benign (0.202); catalogued as COSV57785855; called by muse, mutect2, varscan2
- ASXL1 | c.4175C>T p.P1392L | Missense Mutation (SNP) | VAF 57/125 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.786); catalogued as COSV60122836; called by muse, mutect2, varscan2
- ASXL3 | c.2797C>T p.R933W | Missense Mutation (SNP) | VAF 26/50 reads (52%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.998); catalogued as rs376307971; called by muse, mutect2, varscan2
- ATG2B | c.1066C>T p.R356* | Nonsense Mutation (SNP) | VAF 24/86 reads (28%) | catalogued as rs775509366, COSV63424831, COSV63425824; called by muse, mutect2, varscan2
- ATG4D | c.1243-1G>A p.X415_splice | Splice Site (SNP) | VAF 33/80 reads (41%) | catalogued as COSV57265959; called by muse, mutect2, varscan2
- ATG9B | c.700C>T p.R234* | Nonsense Mutation (SNP) | VAF 67/234 reads (29%) | catalogued as rs781445782, COSV65057582, COSV65059052; called by muse, mutect2, varscan2
- ATL1 | c.1553G>A p.G518E | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT tolerated (0.45); PolyPhen benign (0.003); catalogued as COSV61205833; called by muse, mutect2, varscan2
- ATP10B | c.2578G>A p.E860K | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); catalogued as COSV59143159; called by muse, mutect2, varscan2
- ATP10D | c.640G>A p.G214R | Missense Mutation (SNP) | VAF 13/59 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56713365; called by muse, mutect2, varscan2
- ATP13A4 | c.2500G>A p.E834K | Missense Mutation (SNP) | VAF 31/84 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV61327673; called by muse, mutect2, varscan2
- ATP2B2 | c.518G>A p.W173* | Nonsense Mutation (SNP) | VAF 56/206 reads (27%) | catalogued as COSV59507888; called by muse, mutect2, varscan2
- ATP6V0D2 | c.469G>A p.E157K | Missense Mutation (SNP) | VAF 48/77 reads (62%) | SIFT deleterious (0); PolyPhen possibly damaging (0.747); catalogued as rs201622171; called by muse, mutect2, varscan2
- ATP8A1 | c.3487G>A p.E1163K | Missense Mutation (SNP) | VAF 5/10 reads (50%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0.001); catalogued as rs751157914, COSV52533125, COSV52543860; called by muse, mutect2, varscan2
- ATP8A1 | c.1868G>A p.R623Q | Missense Mutation (SNP) | VAF 12/20 reads (60%) | SIFT tolerated (0.31); PolyPhen benign (0.017); catalogued as rs1330464217, COSV100046130, COSV52545628; called by muse, mutect2, varscan2
- ATP9B | c.1895C>T p.P632L | Missense Mutation (SNP) | VAF 26/66 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56962239; called by muse, mutect2, varscan2
- ATRIP | c.1112C>T p.S371F | Missense Mutation (SNP) | VAF 51/77 reads (66%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.804); catalogued as COSV56498102; called by muse, mutect2, varscan2
- ATRN | c.946C>T p.P316S | Missense Mutation (SNP) | VAF 32/68 reads (47%) | SIFT tolerated (0.1); PolyPhen benign (0.044); catalogued as COSV53534809; called by muse, mutect2, varscan2
- ATXN1 | c.2365C>T p.P789S | Missense Mutation (SNP) | VAF 21/108 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV55232034; called by muse, mutect2, varscan2
- AUTS2 | c.1573C>T p.H525Y | Missense Mutation (SNP) | VAF 10/76 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV61422529; called by muse, mutect2, varscan2
- AWAT1 | c.862G>A p.E288K | Missense Mutation (SNP) | VAF 21/21 reads (100%) | SIFT tolerated (0.25); PolyPhen benign (0.046); catalogued as COSV65739126; called by muse, mutect2, varscan2
- AXDND1 | c.2674C>T p.H892Y | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT tolerated (0.17); PolyPhen benign (0.021); catalogued as COSV62648886; called by muse, mutect2, varscan2
- AXL | c.383C>T p.S128F | Missense Mutation (SNP) | VAF 13/65 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56575263; called by muse, mutect2, varscan2
- AXL | c.1570G>A p.E524K (on ENST00000301178 / NM_021913.5; = p.E515K on NM_001699.6) | Missense Mutation (SNP) | VAF 11/73 reads (15%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.999); catalogued as COSV56575281; called by muse, mutect2, varscan2
- B4GALNT1 | c.877C>T p.R293W | Missense Mutation (SNP) | VAF 30/67 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs769436121, COSV57544986; called by muse, mutect2, varscan2
- BACH2 | c.1669C>T p.L557F | Missense Mutation (SNP) | VAF 20/49 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.548); catalogued as COSV57609798, COSV99999261; called by muse, mutect2, varscan2
- BANK1 | c.1876G>A p.E626K | Missense Mutation (SNP) | VAF 38/104 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.058); catalogued as COSV59839918; called by muse, mutect2, varscan2
- BBS4 | c.482C>T p.A161V | Missense Mutation (SNP) | VAF 15/57 reads (26%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.995); catalogued as COSV51440568; called by muse, mutect2, varscan2
- BBS7 | c.1133C>T p.S378F | Missense Mutation (SNP) | VAF 20/85 reads (24%) | SIFT tolerated (0.7); PolyPhen benign (0.006); catalogued as COSV52659692; called by muse, mutect2, varscan2
- BCAM | c.685G>A p.D229N | Missense Mutation (SNP) | VAF 33/183 reads (18%) | SIFT tolerated (0.13); PolyPhen benign (0.054); catalogued as COSV54305106; called by muse, mutect2, varscan2
- BCAN | c.835G>A p.E279K | Missense Mutation (SNP) | VAF 40/169 reads (24%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.739); catalogued as COSV61256184; called by muse, mutect2, varscan2
- BCL11A | c.956C>T p.P319L (on ENST00000335712 / NM_001365609.1; = p.P353L on NM_018014.4) | Missense Mutation (SNP) | VAF 96/729 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV59637495; called by muse, mutect2, varscan2
- BCL11A | c.121G>A p.G41R | Missense Mutation (SNP) | VAF 113/1048 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.998); catalogued as COSV59625764; called by muse, mutect2, varscan2
- BCL11B | c.257G>A p.G86D | Missense Mutation (SNP) | VAF 9/73 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.074); catalogued as COSV61739672; called by muse, mutect2, varscan2
- BCL3 | c.646C>T p.R216C | Missense Mutation (SNP) | VAF 25/70 reads (36%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.523); catalogued as rs1481704544, COSV51234236; called by muse, mutect2, varscan2
- BCL6 | c.418C>T p.R140C | Missense Mutation (SNP) | VAF 23/78 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.609); catalogued as rs779270221, COSV51655927; called by muse, mutect2, varscan2
- BCO2 | c.743C>T p.S248F | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT tolerated (0.75); PolyPhen benign (0.003); catalogued as COSV63065108; called by muse, mutect2, varscan2
- BCORL1 | c.3832C>T p.R1278C | Missense Mutation (SNP) | VAF 47/52 reads (90%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs908085298, COSV54401572; called by muse, mutect2, varscan2
- BCR | c.19T>C p.F7L | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.973); catalogued as rs1233802398, COSV100007117; called by muse, mutect2, varscan2
- BEND2 | c.473G>A p.G158E | Missense Mutation (SNP) | VAF 23/50 reads (46%) | SIFT tolerated (0.08); PolyPhen benign (0.076); catalogued as rs866322579, COSV66217381; called by muse, mutect2, varscan2
- BET1L | c.169-6C>T | Splice Region (SNP) | VAF 25/48 reads (52%) | catalogued as COSV100254954; called by muse, mutect2, varscan2
- BHMT | c.38T>A p.I13N | Missense Mutation (SNP) | VAF 32/56 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV57155870; called by muse, mutect2, varscan2
- BICD1 | c.2675C>T p.S892L | Missense Mutation (SNP) | VAF 56/145 reads (39%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.111); catalogued as COSV55688711; called by muse, mutect2, varscan2
- BIRC3 | c.1775G>A p.R592K | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV54820101; called by muse, mutect2, varscan2
- BIVM-ERCC5 | c.869C>T p.P290L | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV57282832; called by muse, mutect2, varscan2
- BMP5 | c.938G>A p.R313Q | Missense Mutation (SNP) | VAF 18/92 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63702532, COSV63706127; called by muse, mutect2, varscan2
- BMP6 | c.623T>C p.F208S | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.985); catalogued as rs750654076, COSV51672719; called by muse, mutect2, varscan2
- BMPER | c.1849C>T p.H617Y | Missense Mutation (SNP) | VAF 39/92 reads (42%) | SIFT tolerated (0.77); PolyPhen benign (0.29); catalogued as COSV51832005; called by muse, mutect2, varscan2
- BMPR2 | c.23C>T p.P8L | Missense Mutation (SNP) | VAF 21/83 reads (25%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV65813614; called by muse, mutect2, varscan2
- BNC1 | c.184G>A p.G62R | Missense Mutation (SNP) | VAF 50/98 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61759270; called by muse, varscan2
- BNIP5 | c.178G>A p.D60N | Missense Mutation (SNP) | VAF 21/104 reads (20%) | SIFT tolerated (0.18); PolyPhen benign (0.024); catalogued as COSV71325865; called by muse, mutect2, varscan2
- BPNT2 | c.637G>A p.E213K | Missense Mutation (SNP) | VAF 19/121 reads (16%) | SIFT tolerated (0.84); PolyPhen benign (0.003); catalogued as rs770658609, COSV52908146; called by muse, mutect2, varscan2
- BRCA2 | c.9755C>T p.S3252F | Missense Mutation (SNP) | VAF 34/105 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV66337976; called by muse, mutect2, varscan2
- BRINP1 | c.1669G>A p.D557N | Missense Mutation (SNP) | VAF 29/31 reads (94%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV56313902; called by muse, mutect2, varscan2
- BRINP2 | c.196C>T p.H66Y | Missense Mutation (SNP) | VAF 56/128 reads (44%) | SIFT tolerated (0.06); PolyPhen benign (0.013); catalogued as rs112761040, COSV64180487; called by muse, mutect2, varscan2
- BRINP2 | c.377G>A p.G126E | Missense Mutation (SNP) | VAF 49/121 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64180491; called by muse, mutect2, varscan2
- BRINP2 | c.1093G>A p.D365N | Missense Mutation (SNP) | VAF 52/281 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV64180494; called by muse, varscan2
- BRINP2 | c.1162C>T p.R388W | Missense Mutation (SNP) | VAF 70/134 reads (52%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.451); catalogued as rs138472115; called by muse, varscan2
- BRIP1 | c.1931C>T p.S644L | Missense Mutation (SNP) | VAF 49/105 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52009305; called by muse, mutect2, varscan2
- BRPF3 | c.1484G>A p.R495K | Missense Mutation (SNP) | VAF 30/151 reads (20%) | SIFT tolerated (0.36); PolyPhen benign (0.007); catalogued as COSV60209982; called by muse, mutect2, varscan2
- BTBD16 | c.298C>T p.Q100* | Nonsense Mutation (SNP) | VAF 37/132 reads (28%) | catalogued as COSV53267183; called by muse, mutect2, varscan2
- BTBD7 | c.3119C>T p.P1040L | Missense Mutation (SNP) | VAF 51/205 reads (25%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.01); catalogued as COSV58290747; called by muse, mutect2, varscan2
- C10orf71 | c.517C>T p.P173S | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT tolerated (0.61); PolyPhen benign (0.019); catalogued as COSV60504430; called by muse, mutect2, varscan2
- C11orf16 | c.1337G>A p.G446E | Missense Mutation (SNP) | VAF 25/109 reads (23%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV55149385; called by muse, mutect2, varscan2
- C11orf24 | c.962C>T p.S321F | Missense Mutation (SNP) | VAF 12/65 reads (18%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.947); catalogued as rs751098283, COSV58505532, COSV58506347; called by muse, mutect2, varscan2
- C14orf39 | c.1109G>A p.G370E | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT tolerated (0.33); PolyPhen benign (0.003); catalogued as rs1566665387, COSV58779599, COSV58780823; called by muse, mutect2, varscan2
- C16orf92 | c.355C>T p.L119F | Missense Mutation (SNP) | VAF 28/81 reads (35%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.46); catalogued as rs780476731, COSV54228206, COSV54228303; called by muse, mutect2, varscan2
- C1orf127 | c.2387C>T p.P796L | Missense Mutation (SNP) | VAF 21/22 reads (95%) | SIFT tolerated (0.06); PolyPhen benign (0.028); catalogued as rs1012992840, COSV65439094; called by muse, varscan2
- C22orf31 | c.744G>A p.W248* | Nonsense Mutation (SNP) | VAF 22/94 reads (23%) | catalogued as rs1385567215, COSV99326494; called by muse, mutect2, varscan2
- C22orf31 | c.743G>A p.W248* | Nonsense Mutation (SNP) | VAF 22/93 reads (24%) | catalogued as COSV99326537; called by muse, mutect2, varscan2
- C2orf66 | c.89G>A p.W30* | Nonsense Mutation (SNP) | VAF 64/224 reads (29%) | catalogued as rs1357130130, COSV61099249; called by muse, mutect2, varscan2
- C3orf14 | c.325C>T p.P109S | Missense Mutation (SNP) | VAF 31/44 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as COSV51707683; called by muse, mutect2, varscan2
- C4A | c.3512C>T p.S1171F | Missense Mutation (SNP) | VAF 28/204 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV71178984; called by muse, varscan2
- C4orf45 | c.541G>A p.E181K | Missense Mutation (SNP) | VAF 19/31 reads (61%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.018); catalogued as COSV71700717; called by muse, mutect2, varscan2
- C5AR1 | c.941C>T p.S314F | Missense Mutation (SNP) | VAF 26/111 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV61893542; called by muse, varscan2
- C7 | c.1348G>A p.D450N | Missense Mutation (SNP) | VAF 12/68 reads (18%) | SIFT tolerated (0.48); PolyPhen benign (0.236); catalogued as COSV100495357, COSV57481506; called by muse, varscan2
- C7orf31 | c.1064C>T p.S355F | Missense Mutation (SNP) | VAF 29/272 reads (11%) | SIFT tolerated (0.19); PolyPhen benign (0.078); catalogued as COSV52220263; called by muse, mutect2, varscan2
- C8A | c.950C>T p.S317L | Missense Mutation (SNP) | VAF 20/34 reads (59%) | SIFT deleterious (0); PolyPhen possibly damaging (0.811); catalogued as rs563439122, COSV63486606; called by muse, mutect2, varscan2
- C8A | c.1249G>A p.E417K | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT tolerated (0.19); PolyPhen benign (0.031); catalogued as COSV63485845; called by muse, mutect2, varscan2
- C8orf74 | c.311C>T p.T104I | Missense Mutation (SNP) | VAF 65/176 reads (37%) | SIFT tolerated (0.13); PolyPhen benign (0.11); catalogued as COSV100262434; called by muse, mutect2, varscan2
- C9orf43 | c.455G>A p.G152E | Missense Mutation (SNP) | VAF 17/27 reads (63%) | SIFT tolerated (0.71); PolyPhen benign (0.043); catalogued as COSV55914269; called by muse, mutect2, varscan2
- CA1 | c.17G>A p.W6* | Nonsense Mutation (SNP) | VAF 10/61 reads (16%) | catalogued as COSV56280180; called by muse, mutect2, varscan2
- CA10 | c.109G>A p.E37K | Missense Mutation (SNP) | VAF 18/105 reads (17%) | SIFT tolerated (0.18); PolyPhen benign (0.251); catalogued as COSV53339803, COSV53373955; called by muse, mutect2, varscan2
- CA2 | c.556G>A p.E186K | Missense Mutation (SNP) | VAF 122/202 reads (60%) | SIFT tolerated (0.98); PolyPhen benign (0); catalogued as COSV53408411, COSV53408535; called by muse, mutect2
- CABP4 | c.298C>T p.R100C | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.719); catalogued as rs966008036, COSV56885213; called by muse, mutect2, varscan2
- CABP4 | c.671G>A p.G224E | Missense Mutation (SNP) | VAF 23/63 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57800192; called by muse, mutect2, varscan2
- CACNA1B | c.973G>A p.D325N | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.176); catalogued as COSV53150093; called by muse, mutect2, varscan2
- CACNA1D | c.5950C>T p.P1984S (on ENST00000350061 / NM_001128840.3; = p.P2004S on NM_000720.4) | Missense Mutation (SNP) | VAF 15/69 reads (22%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.722); catalogued as rs926241141, COSV55465819; called by muse, mutect2, varscan2
- CACNA1E | c.1591G>A p.G531R | Missense Mutation (SNP) | VAF 17/52 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62426423; called by muse, mutect2, varscan2
- CACNA1E | c.3226G>A p.D1076N | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT tolerated (0.52); PolyPhen benign (0.443); catalogued as rs945186367, COSV62426448; called by muse, mutect2
- CACNA1F | c.5198G>A p.G1733E | Missense Mutation (SNP) | VAF 9/11 reads (82%) | SIFT tolerated (0.39); PolyPhen benign (0.074); catalogued as COSV59903938; called by muse, mutect2, varscan2
- CACNA1H | c.6283G>A p.D2095N | Missense Mutation (SNP) | VAF 14/27 reads (52%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.994); catalogued as COSV52358570; called by muse, mutect2, varscan2
- CACNA1I | c.4925G>A p.G1642E | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60818986; called by muse, mutect2
- CACNA1S | c.2341A>C p.I781L | Missense Mutation (SNP) | VAF 63/122 reads (52%) | SIFT tolerated (0.08); PolyPhen benign (0.079); catalogued as COSV62943960; called by muse, mutect2, varscan2
- CACNA2D3 | c.451G>A p.E151K | Missense Mutation (SNP) | VAF 51/82 reads (62%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs552100021, COSV55568277; called by muse, mutect2, varscan2
- CACNA2D3 | c.865G>A p.D289N | Missense Mutation (SNP) | VAF 68/177 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.027); catalogued as COSV55584161; called by muse, mutect2, varscan2
- CACNA2D4 | c.1165G>A p.E389K | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT tolerated (0.31); PolyPhen benign (0.345); catalogued as COSV54961392; called by muse, mutect2, varscan2
- CACNG3 | c.704C>T p.S235L | Missense Mutation (SNP) | VAF 22/41 reads (54%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.931); catalogued as COSV50084430; called by muse, varscan2
- CACNG3 | c.728G>A p.R243K | Missense Mutation (SNP) | VAF 26/45 reads (58%) | SIFT tolerated (0.7); PolyPhen benign (0.076); catalogued as COSV50084521; called by muse, varscan2
- CACNG3 | c.734G>A p.R245Q | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.732); catalogued as rs746004181, COSV50065372; called by muse, varscan2
- CADM1 | c.454C>T p.Q152* | Nonsense Mutation (SNP) | VAF 42/50 reads (84%) | catalogued as COSV59023876; called by muse, mutect2, varscan2
- CADM2 | c.248C>T p.S83F (on ENST00000407528 / NM_001167674.2; = p.S85F on NM_153184.4) | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV67391723; called by muse, mutect2, varscan2
- CADM2 | c.971C>T p.T324I (on ENST00000407528 / NM_001167674.2; = p.T326I on NM_153184.4) | Missense Mutation (SNP) | VAF 39/163 reads (24%) | SIFT tolerated (0.13); PolyPhen benign (0.018); catalogued as COSV67406006; called by muse, mutect2, varscan2
- CADM2 | c.1103C>T p.A368V (on ENST00000407528 / NM_001167674.2; = p.A370V on NM_153184.4) | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV67406010; called by muse, mutect2, varscan2
- CADPS | c.4048G>A p.E1350K | Missense Mutation (SNP) | VAF 20/98 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.107); catalogued as rs147103435, COSV51901025; called by muse, varscan2
- CADPS | c.3388G>A p.V1130I | Missense Mutation (SNP) | VAF 32/84 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV51904372; called by muse, mutect2, varscan2
- CALCR | c.228G>A p.W76* | Nonsense Mutation (SNP) | VAF 15/40 reads (38%) | catalogued as COSV64012161; called by muse, mutect2, varscan2
- CALML5 | c.187G>A p.E63K | Missense Mutation (SNP) | VAF 50/93 reads (54%) | SIFT tolerated (0.07); PolyPhen benign (0.025); catalogued as COSV66702509; called by muse, mutect2, varscan2
- CAMK2A | c.893A>G p.K298R | Missense Mutation (SNP) | VAF 30/44 reads (68%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.982); catalogued as COSV62247853; called by muse, mutect2, varscan2
- CAMK4 | c.631G>A p.E211K | Missense Mutation (SNP) | VAF 27/74 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV56667407; called by muse, mutect2, varscan2
- CAMSAP1 | c.3029C>T p.T1010I | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT tolerated (0.28); PolyPhen benign (0.047); catalogued as COSV56728762; called by muse, mutect2, varscan2
- CAND1 | c.371C>T p.S124F | Missense Mutation (SNP) | VAF 23/56 reads (41%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.59); catalogued as COSV73338670, COSV99075097; called by muse, mutect2, varscan2
- CAP2 | c.887G>A p.G296E | Missense Mutation (SNP) | VAF 63/173 reads (36%) | SIFT tolerated (0.06); PolyPhen benign (0.355); catalogued as rs747149347, COSV57737353; called by muse, mutect2, varscan2
- CAPN13 | c.845G>A p.W282* | Nonsense Mutation (SNP) | VAF 4/44 reads (9%) | catalogued as rs1419434175, COSV54435724; called by muse, mutect2
- CAPZA3 | c.74G>A p.G25E | Missense Mutation (SNP) | VAF 11/76 reads (14%) | SIFT tolerated (0.09); PolyPhen probably damaging (1); catalogued as COSV99856427; called by muse, mutect2, varscan2
- CAPZA3 | c.510G>A p.W170* | Nonsense Mutation (SNP) | VAF 23/45 reads (51%) | catalogued as rs868010711, COSV56850834; called by muse, mutect2, varscan2
- CARD11 | c.1585G>A p.E529K | Missense Mutation (SNP) | VAF 30/114 reads (26%) | SIFT tolerated (0.42); PolyPhen benign (0.013); catalogued as COSV62757196; called by muse, mutect2, varscan2
- CARD14 | c.1478G>A p.G493E | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT tolerated (0.32); PolyPhen benign (0.007); catalogued as COSV100712467, COSV60126940; called by muse, mutect2, varscan2
- CARD6 | c.1930G>A p.E644K | Missense Mutation (SNP) | VAF 62/317 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.223); catalogued as COSV54569249; called by muse, mutect2, varscan2
- CASC3 | c.1694C>T p.A565V | Missense Mutation (SNP) | VAF 90/208 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.022); catalogued as COSV52866909; called by muse, mutect2, varscan2
- CASKIN2 | c.3295G>A p.G1099R | Missense Mutation (SNP) | VAF 31/181 reads (17%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.898); catalogued as COSV58600352; called by muse, mutect2, varscan2
- CASS4 | c.964C>T p.P322S | Missense Mutation (SNP) | VAF 29/86 reads (34%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as rs865932743, COSV64388464; called by muse, mutect2, varscan2
- CASS4 | c.1822T>A p.C608S | Missense Mutation (SNP) | VAF 8/69 reads (12%) | SIFT tolerated (0.27); PolyPhen benign (0.089); catalogued as COSV64388589; called by mutect2, varscan2
- CATSPER1 | c.2245G>A p.V749M | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); catalogued as rs370395617; called by muse, mutect2, varscan2
- CATSPER1 | c.749A>T p.H250L | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT tolerated (0.45); PolyPhen benign (0.025); catalogued as COSV56413690; called by muse, mutect2
- CATSPER1 | c.307G>A p.G103S | Missense Mutation (SNP) | VAF 61/162 reads (38%) | SIFT tolerated (0.22); PolyPhen benign (0.019); catalogued as rs1248844679, COSV56413701; called by muse, mutect2, varscan2
- CATSPER4 | c.1088G>A p.G363E | Missense Mutation (SNP) | VAF 56/66 reads (85%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.881); catalogued as rs1420151559, COSV58794617; called by muse, mutect2, varscan2
- CAVIN2 | c.853G>A p.G285R | Missense Mutation (SNP) | VAF 51/200 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.907); catalogued as COSV58425639, COSV58426010; called by muse, mutect2, varscan2
- CBLC | c.298C>T p.P100S | Missense Mutation (SNP) | VAF 55/195 reads (28%) | SIFT tolerated (0.09); PolyPhen benign (0.005); catalogued as rs1568554125, COSV54326015; called by muse, varscan2
- CBLC | c.311G>A p.R104K | Missense Mutation (SNP) | VAF 76/179 reads (42%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1035887672, COSV54326028; called by muse, varscan2
- CBLC | c.376A>C p.I126L | Missense Mutation (SNP) | VAF 120/239 reads (50%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV54326041; called by muse, mutect2, varscan2
- CBLL1 | c.1342G>A p.G448R | Missense Mutation (SNP) | VAF 37/85 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as rs1358533532, COSV56030781; called by muse, mutect2, varscan2
- CCDC141 | c.2794G>A p.E932K | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); catalogued as rs267599099, COSV55368178; called by muse, mutect2, varscan2
- CCDC141 | c.2338C>T p.Q780* | Nonsense Mutation (SNP) | VAF 14/55 reads (25%) | catalogued as COSV55382943; called by muse, mutect2, varscan2
- CCDC170 | c.394G>A p.E132K | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.713); catalogued as COSV53346827; called by muse, mutect2, varscan2
- CCDC32 | c.19G>A p.A7T | Missense Mutation (SNP) | VAF 49/204 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as rs779240446, COSV63634563; called by muse, mutect2, varscan2
- CCDC33 | c.1692G>A p.M564I | Missense Mutation (SNP) | VAF 18/78 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.558); catalogued as COSV51503720; called by muse, mutect2, varscan2
- CCDC50 | c.500C>T p.P167L | Missense Mutation (SNP) | VAF 11/62 reads (18%) | SIFT tolerated (0.09); PolyPhen benign (0.059); catalogued as rs761255261, COSV101165376, COSV66669817; called by muse, mutect2
- CCDC74A | c.838C>T p.R280C | Missense Mutation (SNP) | VAF 41/89 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs774819631, COSV54609281; called by muse, mutect2, varscan2
- CCDC81 | c.1004G>A p.R335Q (on ENST00000445632 / NM_001156474.2; = p.R245Q on NM_021827.4) | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT tolerated (0.13); PolyPhen benign (0.037); catalogued as rs868030464, COSV53577858; called by muse, mutect2, varscan2
- CCDC88C | c.4430C>T p.S1477F | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.156); catalogued as COSV58663162; called by muse, mutect2
- CCDC92 | c.694C>T p.L232F | Missense Mutation (SNP) | VAF 23/78 reads (29%) | SIFT tolerated (0.35); PolyPhen benign (0.316); catalogued as COSV53020548; called by muse, mutect2, varscan2
- CCIN | c.745C>T p.H249Y | Missense Mutation (SNP) | VAF 16/19 reads (84%) | SIFT tolerated (0.42); PolyPhen benign (0.099); catalogued as COSV58725791; called by muse, mutect2, varscan2
- CCL7 | c.76+1G>A p.X26_splice | Splice Site (SNP) | VAF 18/41 reads (44%) | catalogued as COSV52337690; called by muse, mutect2
- CCNK | c.411G>A p.K137= | Splice Region (SNP) | VAF 38/195 reads (19%) | catalogued as COSV66275943; called by muse, mutect2, varscan2
- CCNL1 | c.1435C>T p.R479W | Missense Mutation (SNP) | VAF 30/131 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs200316598; called by muse, mutect2, varscan2
- CCT6B | c.1343C>T p.P448L | Missense Mutation (SNP) | VAF 22/156 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.782); catalogued as rs372139870; called by muse, mutect2, varscan2
- CD101 | c.1337G>A p.S446N | Missense Mutation (SNP) | VAF 55/86 reads (64%) | SIFT tolerated (0.39); PolyPhen benign (0.258); catalogued as rs756120682, COSV56721418; called by muse, mutect2, varscan2
- CD101 | c.2039C>T p.S680L | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT tolerated (0.1); PolyPhen benign (0.01); catalogued as COSV56721427; called by muse, mutect2, varscan2
- CD163 | c.3454G>A p.E1152K | Missense Mutation (SNP) | VAF 23/56 reads (41%) | SIFT tolerated (0.17); PolyPhen benign (0.005); catalogued as COSV63130459; called by muse, mutect2, varscan2
- CD163 | c.3224G>A p.R1075Q | Missense Mutation (SNP) | VAF 49/193 reads (25%) | SIFT tolerated (0.61); PolyPhen benign (0.006); catalogued as rs748750295, COSV63133563; called by muse, mutect2, varscan2
- CD163 | c.2245G>A p.D749N | Missense Mutation (SNP) | VAF 31/143 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.129); catalogued as COSV63131638; called by muse, mutect2, varscan2
- CD163L1 | c.695G>A p.W232* | Nonsense Mutation (SNP) | VAF 12/62 reads (19%) | catalogued as COSV58025198; called by muse, mutect2, varscan2
- CD1C | c.265C>T p.R89C | Missense Mutation (SNP) | VAF 22/132 reads (17%) | SIFT deleterious (0.05); PolyPhen benign (0.034); catalogued as rs145638725, COSV63805710, COSV63806016; called by muse, mutect2, varscan2
- CD2 | c.913C>T p.Q305* | Nonsense Mutation (SNP) | VAF 56/140 reads (40%) | catalogued as COSV65644623; called by muse, mutect2, varscan2
- CD276 | c.785C>T p.T262I | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT tolerated (0.18); PolyPhen benign (0.062); catalogued as COSV59205791; called by muse, mutect2, varscan2
- CD2AP | c.934G>A p.E312K | Missense Mutation (SNP) | VAF 8/70 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs147188917; called by mutect2, varscan2
- CD93 | c.941G>A p.G314E | Missense Mutation (SNP) | VAF 12/76 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs202080643, COSV55664001; called by muse, mutect2
- CDC42BPB | c.4955C>T p.T1652I | Missense Mutation (SNP) | VAF 45/116 reads (39%) | SIFT tolerated (0.14); PolyPhen benign (0.017); catalogued as rs746810463, COSV63476942; called by muse, mutect2, varscan2
- CDCP1 | c.314C>T p.P105L | Missense Mutation (SNP) | VAF 129/215 reads (60%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV56108216; called by muse, mutect2, varscan2
- CDH10 | c.2293C>T p.L765F | Missense Mutation (SNP) | VAF 33/146 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52598784; called by muse, varscan2
- CDH10 | c.689G>A p.R230K | Missense Mutation (SNP) | VAF 13/61 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as COSV52577328; called by muse, mutect2, varscan2
- CDH10 | c.395T>A p.I132N | Missense Mutation (SNP) | VAF 91/131 reads (69%) | SIFT deleterious (0); PolyPhen possibly damaging (0.75); catalogued as COSV52598804; called by muse, mutect2, varscan2
- CDH12 | c.2224G>A p.E742K | Missense Mutation (SNP) | VAF 146/176 reads (83%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV66396706, COSV66440665; called by muse, mutect2, varscan2
- CDH12 | c.1199G>A p.G400E | Missense Mutation (SNP) | VAF 6/78 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66447672; called by muse, mutect2
- CDH12 | c.23C>T p.S8F | Missense Mutation (SNP) | VAF 24/133 reads (18%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as rs1211476604, COSV66420319, COSV66423634; called by muse, mutect2
- CDH17 | c.613C>T p.P205S | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT tolerated (0.27); PolyPhen benign (0.12); catalogued as COSV50341497; called by muse, mutect2, varscan2
- CDH19 | c.1105C>T p.L369F | Missense Mutation (SNP) | VAF 13/28 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.078); catalogued as COSV50972966, COSV50978224; called by muse, mutect2, varscan2
- CDH23 | c.9512G>A p.G3171E | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1321844333, COSV56452343; called by muse, mutect2, varscan2
- CDH26 | c.1858C>T p.P620S | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.284); catalogued as COSV54855552; called by muse, mutect2, varscan2
- CDH26 | c.2089G>A p.G697R (on ENST00000348616 / NM_177980.4; = p.G30R on NM_021810.6) | Missense Mutation (SNP) | VAF 14/95 reads (15%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.814); catalogued as COSV54855578; called by muse, mutect2, varscan2
- CDH4 | c.967C>T p.P323S | Missense Mutation (SNP) | VAF 85/150 reads (57%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV64675734; called by muse, mutect2, varscan2
- CDH6 | c.904G>A p.E302K | Missense Mutation (SNP) | VAF 48/62 reads (77%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.632); catalogued as COSV54076372, COSV54078363; called by muse, mutect2, varscan2
- CDH6 | c.1016A>G p.K339R | Missense Mutation (SNP) | VAF 68/93 reads (73%) | SIFT tolerated (0.17); PolyPhen benign (0.155); catalogued as rs769888204, COSV54078868; called by muse, mutect2, varscan2
- CDH9 | c.1336C>T p.L446F | Missense Mutation (SNP) | VAF 19/68 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV50275464, COSV50473125; called by muse, mutect2, varscan2
- CDON | c.866C>T p.S289F | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.305); catalogued as COSV55002770; called by muse, mutect2, varscan2
- CEACAM18 | c.843G>A p.M281I | Missense Mutation (SNP) | VAF 26/122 reads (21%) | SIFT tolerated (0.67); PolyPhen benign (0.001); catalogued as COSV67284263; called by muse, mutect2, varscan2
- CECR2 | c.794C>T p.S265F (on ENST00000342247 / NM_001290047.2; = p.S102F on NM_001290046.1) | Missense Mutation (SNP) | VAF 31/89 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52837752; called by muse, mutect2, varscan2
- CELF3 | c.95G>T p.R32L | Missense Mutation (SNP) | VAF 27/99 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.205); catalogued as COSV51885927; called by muse, mutect2, varscan2
- CELSR1 | c.8767G>A p.E2923K | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.867); catalogued as COSV53083287; called by muse, mutect2, varscan2
- CELSR1 | c.826G>A p.E276K | Missense Mutation (SNP) | VAF 27/72 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.851); catalogued as COSV53100462; called by muse, mutect2, varscan2
- CELSR2 | c.2454C>A p.D818E | Missense Mutation (SNP) | VAF 107/277 reads (39%) | SIFT tolerated (0.27); PolyPhen benign (0.049); catalogued as COSV54779733; called by muse, mutect2, varscan2
- CELSR2 | c.5264C>A p.A1755D | Missense Mutation (SNP) | VAF 135/293 reads (46%) | SIFT tolerated (0.66); PolyPhen benign (0.009); catalogued as COSV54779743; called by muse, mutect2, varscan2
- CEND1 | c.335G>A p.G112E | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.047); catalogued as rs780959582, COSV57195132; called by muse, mutect2, varscan2
- CENPA | c.277G>A p.A93T | Missense Mutation (SNP) | VAF 16/98 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV51983505; called by muse, mutect2, varscan2
- CENPE | c.6722A>G p.E2241G | Missense Mutation (SNP) | VAF 46/142 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.555); catalogued as COSV54390867; called by muse, mutect2, varscan2
- CENPJ | c.2491A>T p.I831L | Missense Mutation (SNP) | VAF 24/48 reads (50%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as COSV67883177, COSV67884312; called by muse, mutect2, varscan2
- CEP164 | c.3784C>T p.H1262Y | Missense Mutation (SNP) | VAF 34/82 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.005); catalogued as COSV54046563; called by muse, mutect2, varscan2
- CEP350 | c.8221G>A p.E2741K | Missense Mutation (SNP) | VAF 24/63 reads (38%) | SIFT tolerated (0.06); PolyPhen benign (0.223); catalogued as COSV62610015; called by muse, mutect2, varscan2
- CES1 | c.316G>A p.E106K | Missense Mutation (SNP) | VAF 45/225 reads (20%) | SIFT tolerated (0.11); PolyPhen benign (0.44); catalogued as COSV62090435; called by muse, mutect2, varscan2
- CFAP206 | c.1658T>C p.V553A | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT tolerated (0.46); PolyPhen benign (0.006); catalogued as COSV65810767; called by muse, mutect2, varscan2
- CFAP300 | c.466G>A p.E156K | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.669); catalogued as rs267602669, COSV71570580, COSV71571017; called by muse, mutect2, varscan2
- CFAP43 | c.4558G>A p.D1520N | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.895); catalogued as COSV63855068; called by muse, mutect2
- CFAP46 | c.514G>A p.E172K | Missense Mutation (SNP) | VAF 47/79 reads (59%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.497); catalogued as COSV63955167; called by muse, mutect2, varscan2
- CFAP54 | c.5000G>A p.S1667N | Missense Mutation (SNP) | VAF 17/29 reads (59%) | SIFT tolerated (0.23); PolyPhen benign (0.009); catalogued as COSV61575462; called by muse, mutect2, varscan2
- CFAP54 | c.7115C>T p.S2372F | Missense Mutation (SNP) | VAF 7/13 reads (54%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.697); catalogued as rs894088687, COSV61570780; called by muse, mutect2, varscan2
- CFAP58 | c.562C>T p.R188* | Nonsense Mutation (SNP) | VAF 7/31 reads (23%) | catalogued as rs199948952; called by muse, mutect2, varscan2
- CFAP65 | c.4612G>A p.E1538K | Missense Mutation (SNP) | VAF 17/59 reads (29%) | SIFT tolerated (0.16); PolyPhen benign (0.044); catalogued as COSV100445987; called by muse, mutect2, varscan2
- CFAP74 | c.1123A>C p.K375Q | Missense Mutation (SNP) | VAF 28/82 reads (34%) | SIFT tolerated (0.08); PolyPhen benign (0.012); catalogued as COSV54574396; called by muse, mutect2, varscan2
- CFAP77 | c.601C>T p.P201S | Missense Mutation (SNP) | VAF 20/41 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.911); catalogued as COSV58009404; called by muse, mutect2, varscan2
- CFH | c.2161G>A p.E721K | Missense Mutation (SNP) | VAF 16/112 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs774463487, COSV66413924; called by muse, varscan2
- CFHR2 | c.350G>A p.G117E | Missense Mutation (SNP) | VAF 18/128 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66381748; called by muse, mutect2, varscan2
- CFHR4 | c.1592G>A p.G531E (on ENST00000367416 / NM_001201551.2; = p.G285E on NM_006684.5) | Missense Mutation (SNP) | VAF 8/63 reads (13%) | SIFT tolerated (0.27); PolyPhen benign (0.379); catalogued as COSV52224734; called by muse, mutect2, varscan2
- CFLAR | c.1159G>C p.A387P | Missense Mutation (SNP) | VAF 20/32 reads (63%) | SIFT tolerated (0.25); PolyPhen benign (0.003); catalogued as COSV58582256; called by muse, mutect2, varscan2
- CFTR | c.1532C>T p.S511F | Missense Mutation (SNP) | VAF 23/64 reads (36%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.784); catalogued as COSV50048947; called by muse, mutect2, varscan2
- CGNL1 | c.1792G>A p.G598R | Missense Mutation (SNP) | VAF 9/71 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.16); catalogued as COSV55563998; called by muse, mutect2, varscan2
- CHD5 | c.3035G>A p.G1012D | Missense Mutation (SNP) | VAF 37/122 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV52422037; called by muse, mutect2, varscan2
- CHD6 | c.4561C>T p.P1521S | Missense Mutation (SNP) | VAF 19/90 reads (21%) | SIFT tolerated (0.18); PolyPhen benign (0.001); catalogued as COSV64694713; called by muse, mutect2, varscan2
- CHD7 | c.8717C>T p.S2906F | Missense Mutation (SNP) | VAF 25/99 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); catalogued as COSV71114826; called by muse, mutect2, varscan2
- CHD8 | c.6791C>A p.T2264K (on ENST00000646647 / NM_001170629.2; = p.T1985K on NM_020920.4) | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.021); catalogued as COSV63037505; called by muse, mutect2, varscan2
- CHD8 | c.2284G>A p.E762K (on ENST00000646647 / NM_001170629.2; = p.E483K on NM_020920.4) | Missense Mutation (SNP) | VAF 37/84 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67872852; called by muse, mutect2, varscan2
- CHD9 | c.2815C>T p.H939Y | Missense Mutation (SNP) | VAF 46/105 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV54616653; called by muse, mutect2, varscan2
- CHFR | c.1072C>T p.L358F (on ENST00000432561 / NM_001161345.1; = p.L317F on NM_018223.2) | Missense Mutation (SNP) | VAF 23/77 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV57175071, COSV57178292; called by muse, varscan2
- CHGB | c.899C>T p.P300L | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT tolerated (0.13); PolyPhen benign (0.045); catalogued as rs978770464, COSV66761820; called by muse, mutect2, varscan2
- CHIT1 | c.1363G>A p.V455M | Missense Mutation (SNP) | VAF 25/165 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV55150045; called by muse, mutect2, varscan2
- CHL1 | c.501G>A p.M167I | Missense Mutation (SNP) | VAF 20/48 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.876); catalogued as COSV56595770; called by muse, varscan2
- CHODL | c.289G>A p.G97S | Missense Mutation (SNP) | VAF 30/116 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV54735447; called by muse, mutect2, varscan2
- CHORDC1 | c.385G>A p.A129T | Missense Mutation (SNP) | VAF 46/128 reads (36%) | SIFT tolerated (0.06); PolyPhen benign (0.081); catalogued as COSV57707029; called by muse, mutect2, varscan2
- CHP2 | c.265C>T p.H89Y | Missense Mutation (SNP) | VAF 22/40 reads (55%) | SIFT deleterious (0.05); PolyPhen benign (0.028); catalogued as COSV55650940; called by muse, mutect2, varscan2
- CHP2 | c.552G>A p.M184I | Missense Mutation (SNP) | VAF 27/112 reads (24%) | SIFT tolerated (0.14); PolyPhen benign (0.012); catalogued as rs769021555, COSV100270303; called by muse, mutect2, varscan2
- CHP2 | c.553G>A p.D185N | Missense Mutation (SNP) | VAF 26/111 reads (23%) | SIFT tolerated (0.37); PolyPhen benign (0.003); catalogued as COSV100270304; called by muse, mutect2, varscan2
- CHRNA4 | c.578A>G p.N193S | Missense Mutation (SNP) | VAF 15/99 reads (15%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as COSV64720842; called by muse, mutect2, varscan2
- CHRNA5 | c.175G>A p.E59K | Missense Mutation (SNP) | VAF 47/81 reads (58%) | SIFT deleterious (0); PolyPhen benign (0.36); catalogued as rs543210727, COSV55137351; called by muse, mutect2, varscan2
- CHTF18 | c.2922G>C p.L974F | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.869); catalogued as COSV50211033; called by muse, mutect2, varscan2
- CIB3 | c.378G>A p.W126* | Nonsense Mutation (SNP) | VAF 19/89 reads (21%) | catalogued as rs748110114, COSV54167758; called by muse, mutect2, varscan2
- CIC | c.2587C>T p.R863C | Missense Mutation (SNP) | VAF 30/43 reads (70%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.898); catalogued as rs371262812; called by muse, mutect2, varscan2
- CILP | c.1033C>T p.H345Y | Missense Mutation (SNP) | VAF 40/158 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.616); catalogued as COSV56028138; called by muse, mutect2, varscan2
- CKAP5 | c.236C>T p.A79V | Missense Mutation (SNP) | VAF 36/84 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs1457813887, COSV56374347; called by muse, mutect2, varscan2
- CLCA2 | c.1340C>T p.S447L | Missense Mutation (SNP) | VAF 21/52 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.272); catalogued as rs1022166469, COSV65288885; called by muse, mutect2, varscan2
- CLCN2 | c.2446G>A p.D816N | Missense Mutation (SNP) | VAF 40/173 reads (23%) | SIFT tolerated (0.94); PolyPhen probably damaging (0.991); catalogued as COSV55604508; called by muse, mutect2, varscan2
- CLCNKA | c.2053G>A p.A685T | Missense Mutation (SNP) | VAF 24/30 reads (80%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.003); catalogued as COSV58894102; called by muse, mutect2, varscan2
- CLDN4 | c.421C>T p.H141Y | Missense Mutation (SNP) | VAF 37/62 reads (60%) | SIFT deleterious (0); PolyPhen benign (0.01); catalogued as COSV52897275; called by muse, mutect2, varscan2
- CLEC1A | c.305C>T p.S102F | Missense Mutation (SNP) | VAF 22/74 reads (30%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.859); catalogued as COSV59531360, COSV59534151; called by muse, mutect2, varscan2
- CLECL1 | c.269C>A p.T90N | Missense Mutation (SNP) | VAF 22/90 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.538); catalogued as COSV59932126; called by muse, mutect2, varscan2
- CLGN | c.1086G>A p.M362I | Missense Mutation (SNP) | VAF 21/77 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.092); catalogued as rs1413335502, COSV57776601; called by muse, mutect2, varscan2
- CLIP1 | c.1019C>T p.S340F | Missense Mutation (SNP) | VAF 31/67 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56801915; called by muse, mutect2, varscan2
- CLMN | c.1132G>A p.E378K | Missense Mutation (SNP) | VAF 25/84 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.171); catalogued as rs371811881; called by muse, mutect2, varscan2
- CLPTM1 | c.291C>G p.F97L | Missense Mutation (SNP) | VAF 101/240 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.978); catalogued as COSV61613237; called by muse, mutect2, varscan2
- CLSTN2 | c.2012C>T p.T671I | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT tolerated (0.18); PolyPhen benign (0.015); catalogued as COSV71725380; called by muse, varscan2
- CLUH | c.2635G>A p.G879R (on ENST00000435359; = p.G918R on NM_015229.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT tolerated (0.47); PolyPhen benign (0.094); catalogued as COSV70930145; called by muse, mutect2, varscan2
- CLVS1 | c.391G>A p.E131K | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT tolerated (0.72); PolyPhen benign (0.062); catalogued as rs1254755181, COSV57975251; called by muse, mutect2, varscan2
- CLVS1 | c.535G>A p.G179S | Missense Mutation (SNP) | VAF 28/73 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57983562; called by muse, mutect2, varscan2
- CMKLR1 | c.1117C>T p.L373F (on ENST00000312143 / NM_001142344.2; = p.L371F on NM_004072.3) | Missense Mutation (SNP) | VAF 36/143 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.042); catalogued as COSV56442081; called by muse, mutect2, varscan2
- CMYA5 | c.283C>T p.P95S | Missense Mutation (SNP) | VAF 85/145 reads (59%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.813); catalogued as rs1234849234, COSV71409674; called by muse, mutect2, varscan2
- CMYA5 | c.4133C>T p.S1378F | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); catalogued as COSV71406078; called by muse, mutect2, varscan2
- CNGA1 | c.1396C>A p.H466N | Missense Mutation (SNP) | VAF 35/107 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.171); catalogued as COSV62057113; called by muse, varscan2
- CNGA3 | c.157G>A p.E53K | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.026); catalogued as COSV55628455; called by muse, mutect2, varscan2
- CNGB3 | c.1168G>A p.E390K | Missense Mutation (SNP) | VAF 16/62 reads (26%) | SIFT tolerated (0.48); PolyPhen benign (0.058); catalogued as COSV60696071, COSV60698843; called by muse, mutect2, varscan2
- CNOT6L | c.38C>T p.P13L (on ENST00000504123 / NM_001286790.2; = p.P8L on NM_144571.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 28/77 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.4); catalogued as rs1445843984, COSV53703595; called by muse, mutect2
- CNTN4 | c.706C>T p.P236S | Missense Mutation (SNP) | VAF 12/24 reads (50%) | SIFT tolerated (0.74); PolyPhen benign (0.021); catalogued as rs945319960, COSV61881584; called by muse, mutect2, varscan2
- CNTN4 | c.970G>A p.D324N | Missense Mutation (SNP) | VAF 15/66 reads (23%) | SIFT tolerated (0.22); PolyPhen benign (0.305); catalogued as rs866962624, COSV100639813, COSV61869280, COSV61878596; called by muse, mutect2, varscan2
- CNTN5 | c.68C>T p.S23F | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV54298591, COSV54325419; called by muse, mutect2
- CNTN6 | c.2728A>T p.I910F | Missense Mutation (SNP) | VAF 22/28 reads (79%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV63190607; called by muse, mutect2, varscan2
- CNTNAP2 | c.1085G>A p.G362E | Missense Mutation (SNP) | VAF 43/102 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.227); catalogued as COSV62144663, COSV62167074; called by muse, mutect2, varscan2
- CNTNAP3 | c.1802C>T p.P601L | Missense Mutation (SNP) | VAF 35/39 reads (90%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as rs1374325132, COSV52676102, COSV99905386; called by muse, mutect2, varscan2
- CNTNAP4 | c.1339G>A p.E447K | Missense Mutation (SNP) | VAF 31/73 reads (42%) | SIFT tolerated (0.06); PolyPhen benign (0.093); catalogued as rs556620057, COSV56680869; called by muse, mutect2, varscan2
- COASY | c.803C>T p.P268L | Missense Mutation (SNP) | VAF 37/91 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.816); catalogued as COSV55900532; called by muse, mutect2, varscan2
- COBL | c.2003C>T p.S668F | Missense Mutation (SNP) | VAF 30/184 reads (16%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.545); catalogued as COSV54339433; called by muse, mutect2, varscan2
- COBLL1 | c.2450C>T p.S817F (on ENST00000392717; = p.S779F on NM_014900.5) | Missense Mutation (SNP) | VAF 29/114 reads (25%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.795); catalogued as COSV52074164; called by muse, mutect2, varscan2
- COG7 | c.712G>A p.E238K | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT tolerated (0.35); PolyPhen benign (0.013); catalogued as COSV56153356; called by muse, mutect2, varscan2
- COL11A1 | c.3176C>T p.P1059L | Missense Mutation (SNP) | VAF 9/16 reads (56%) | SIFT deleterious (0); PolyPhen possibly damaging (0.617); catalogued as COSV62172423, COSV62198672; called by muse, mutect2
- COL11A1 | c.53C>T p.T18I | Missense Mutation (SNP) | VAF 20/23 reads (87%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as COSV62198690; called by muse, mutect2, varscan2
- COL11A2 | c.2144G>A p.G715E (on ENST00000341947 / NM_080680.3; = p.G608E on NM_080679.2) | Missense Mutation (SNP) | VAF 17/59 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59496308; called by muse, mutect2
- COL11A2 | c.91C>T p.P31S | Missense Mutation (SNP) | VAF 21/80 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.006); catalogued as rs1554226286, COSV59493786, COSV59499564; ClinVar: likely benign; called by muse, mutect2, varscan2
- COL14A1 | c.490G>A p.D164N | Missense Mutation (SNP) | VAF 19/91 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs1248831275, COSV52855638; called by muse, mutect2, varscan2
- COL14A1 | c.2355G>A p.M785I | Missense Mutation (SNP) | VAF 67/280 reads (24%) | SIFT tolerated (0.57); PolyPhen benign (0.021); catalogued as COSV52869607; called by muse, mutect2, varscan2
- COL14A1 | c.5288C>T p.S1763L | Missense Mutation (SNP) | VAF 65/105 reads (62%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.977); catalogued as COSV52865949; called by muse, mutect2, varscan2
- COL19A1 | c.3340C>T p.Q1114* | Nonsense Mutation (SNP) | VAF 57/189 reads (30%) | catalogued as COSV59589381; called by muse, mutect2, varscan2
- COL20A1 | c.2108T>C p.V703A | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.438); catalogued as COSV58927861; called by muse, mutect2, varscan2
- COL23A1 | c.1126G>A p.E376K | Missense Mutation (SNP) | VAF 160/224 reads (71%) | SIFT deleterious (0); PolyPhen possibly damaging (0.486); catalogued as rs199565368, COSV101179827; called by muse, mutect2, varscan2
- COL24A1 | c.4039C>T p.P1347S | Missense Mutation (SNP) | VAF 77/84 reads (92%) | SIFT tolerated (0.25); PolyPhen benign (0.028); catalogued as COSV100994055; called by muse, mutect2, varscan2
- COL28A1 | c.1696G>A p.G566R | Missense Mutation (SNP) | VAF 52/142 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1018555099, COSV68081974; called by muse, mutect2, varscan2
- COL2A1 | c.3217C>T p.P1073S | Missense Mutation (SNP) | VAF 31/106 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); catalogued as COSV61534732; called by muse, mutect2, varscan2
- COL2A1 | c.2846C>T p.P949L | Missense Mutation (SNP) | VAF 12/62 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0.086); catalogued as COSV61534739; called by muse, mutect2, varscan2
- COL3A1 | c.3824G>A p.G1275E | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58589425, COSV58596842; called by muse, mutect2
- COL4A2 | c.4313G>A p.G1438E | Missense Mutation (SNP) | VAF 39/59 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64634451; called by muse, mutect2, varscan2
- COL4A3 | c.1109C>T p.P370L | Missense Mutation (SNP) | VAF 22/60 reads (37%) | SIFT tolerated (0.9); PolyPhen benign (0.259); catalogued as COSV67420672; called by muse, mutect2, varscan2
- COL4A3 | c.2639G>A p.G880E | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV67415417; called by muse, mutect2, varscan2
- COL4A4 | c.2153C>T p.P718L | Missense Mutation (SNP) | VAF 23/48 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.42); catalogued as rs1354637374, COSV61636896; called by muse, mutect2, varscan2
- COL5A1 | c.1494G>A p.R498= | Splice Region (SNP) | VAF 51/53 reads (96%) | catalogued as COSV65675208; called by muse, mutect2, varscan2
- COL5A1 | c.3169G>A p.G1057S | Missense Mutation (SNP) | VAF 26/28 reads (93%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV65667425; called by muse, mutect2, varscan2
- COL5A1 | c.3170G>A p.G1057D | Missense Mutation (SNP) | VAF 26/28 reads (93%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1554803568, COSV100880621; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COL5A1 | c.3532C>T p.P1178S | Missense Mutation (SNP) | VAF 48/133 reads (36%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as COSV65675210; called by muse, mutect2, varscan2
- COL6A1 | c.985G>A p.G329R | Missense Mutation (SNP) | VAF 24/47 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs200835287, COSV62615768; ClinVar: likely benign; called by muse, mutect2, varscan2
- COL6A3 | c.6845G>A p.G2282E | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV55089864; called by muse, mutect2, varscan2
- COL6A3 | c.2029C>T p.R677C | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs137923508; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COL8A2 | c.820C>T p.P274S | Missense Mutation (SNP) | VAF 14/15 reads (93%) | SIFT tolerated (0.41); PolyPhen benign (0.109); catalogued as rs747711703, COSV57443601; called by muse, mutect2, varscan2
- COL9A1 | c.2144G>A p.G715E | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV57893727; called by muse, mutect2, varscan2
- COQ8A | c.752C>T p.S251F | Missense Mutation (SNP) | VAF 37/62 reads (60%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.781); catalogued as COSV64658224; called by muse, mutect2, varscan2
- CORIN | c.1942G>A p.D648N | Missense Mutation (SNP) | VAF 23/71 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.025); catalogued as rs1350189599, COSV56699887; called by muse, mutect2, varscan2
- CORO2A | c.131A>G p.N44S | Missense Mutation (SNP) | VAF 34/35 reads (97%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV59665061; called by muse, mutect2, varscan2
- COX15 | c.280G>A p.E94K | Missense Mutation (SNP) | VAF 68/98 reads (69%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.951); catalogued as COSV50013336; called by muse, mutect2, varscan2
- CPAMD8 | c.1408-1G>A p.X470_splice (on ENST00000651564; = p.X423_splice on NM_015692.5) | Splice Site (SNP) | VAF 9/33 reads (27%) | catalogued as COSV52240419; called by muse, mutect2, varscan2
- CPLX3 | c.308G>A p.R103Q | Missense Mutation (SNP) | VAF 30/68 reads (44%) | SIFT tolerated (0.29); PolyPhen benign (0.019); catalogued as rs144213956; called by muse, mutect2, varscan2
- CPNE4 | c.587C>T p.T196I | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); catalogued as COSV70195375; called by muse, mutect2, varscan2
- CPT1A | c.637C>T p.L213F | Missense Mutation (SNP) | VAF 11/65 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.989); catalogued as COSV55761441; called by muse, mutect2, varscan2
- CRACDL | c.385C>T p.Q129* | Nonsense Mutation (SNP) | VAF 32/48 reads (67%) | catalogued as COSV67410277; called by muse, mutect2, varscan2
- CRB1 | c.4130G>A p.G1377E | Missense Mutation (SNP) | VAF 18/96 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1052327653, COSV66349180; called by muse, mutect2, varscan2
- CRB2 | c.1627C>T p.R543W | Missense Mutation (SNP) | VAF 46/49 reads (94%) | SIFT deleterious (0.05); PolyPhen benign (0.003); catalogued as rs146158114; called by muse, mutect2, varscan2
- CREBBP | c.4652A>G p.E1551G | Missense Mutation (SNP) | VAF 14/69 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV52141892; called by muse, mutect2, varscan2
- CREBZF | c.253G>A p.E85K | Missense Mutation (SNP) | VAF 45/117 reads (38%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.003); catalogued as COSV52630741; called by muse, mutect2, varscan2
- CRK | c.431A>T p.N144I | Missense Mutation (SNP) | VAF 24/96 reads (25%) | SIFT tolerated (0.15); PolyPhen benign (0.007); catalogued as COSV56032749; called by muse, mutect2, varscan2
- CRLF2 | c.493G>A p.E165K | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT tolerated (0.83); PolyPhen benign (0.062); catalogued as COSV67493563; called by muse, varscan2
- CRTC1 | c.709C>T p.P237S | Missense Mutation (SNP) | VAF 59/127 reads (46%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.936); catalogued as COSV58723694; called by muse, mutect2, varscan2
- CRYBB3 | c.490C>T p.P164S | Missense Mutation (SNP) | VAF 17/95 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); catalogued as COSV53195560; called by muse, mutect2, varscan2
- CRYBG2 | c.446G>A p.G149E | Missense Mutation (SNP) | VAF 15/33 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV57490435; called by muse, mutect2, varscan2
- CSF1R | c.1725G>A p.W575* | Nonsense Mutation (SNP) | VAF 24/115 reads (21%) | catalogued as COSV53843631; called by muse, mutect2, varscan2
- CSMD1 | c.10375G>A p.D3459N (on ENST00000520002; = p.D3458N on NM_033225.6) | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.631); catalogued as COSV59278090, COSV59387173; called by muse, varscan2
- CSMD1 | c.8842G>A p.E2948K (on ENST00000520002; = p.E2947K on NM_033225.6) | Missense Mutation (SNP) | VAF 64/187 reads (34%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.906); catalogued as COSV59381329; called by muse, mutect2, varscan2
- CSMD1 | c.8355G>A p.W2785* (on ENST00000520002; = p.W2784* on NM_033225.6) | Nonsense Mutation (SNP) | VAF 7/48 reads (15%) | catalogued as COSV59387257; called by muse, mutect2, varscan2
- CSMD1 | c.6088G>A p.E2030K (on ENST00000520002; = p.E2029K on NM_033225.6) | Missense Mutation (SNP) | VAF 31/161 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV59387288; called by muse, mutect2, varscan2
- CSMD1 | c.3829G>A p.E1277K (on ENST00000520002; = p.E1276K on NM_033225.6) | Missense Mutation (SNP) | VAF 14/88 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.115); catalogued as rs534926586, COSV59387361; called by muse, mutect2, varscan2
- CSMD1 | c.3212C>T p.S1071F (on ENST00000520002; = p.S1070F on NM_033225.6) | Missense Mutation (SNP) | VAF 26/110 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.541); catalogued as rs368592556, COSV59302376; called by muse, mutect2, varscan2
- CSMD1 | c.1810G>A p.E604K (on ENST00000520002; = p.E603K on NM_033225.6) | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.994); catalogued as rs749364226, COSV59311456; called by muse, varscan2
- CSMD1 | c.1553C>T p.A518V (on ENST00000520002; = p.A517V on NM_033225.6) | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT tolerated (0.48); PolyPhen possibly damaging (0.6); catalogued as COSV68263178; called by muse, mutect2
- CSMD2 | c.8681G>A p.G2894E | Missense Mutation (SNP) | VAF 10/12 reads (83%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV53952048; called by muse, mutect2, varscan2
- CSMD2 | c.7584T>A p.A2528= | Splice Region (SNP) | VAF 27/31 reads (87%) | catalogued as COSV53966067; called by muse, mutect2, varscan2
- CSMD3 | c.9686G>A p.R3229K (on ENST00000297405 / NM_001363185.1; = p.R3060K on NM_052900.3) | Missense Mutation (SNP) | VAF 31/92 reads (34%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV52184322; called by muse, mutect2, varscan2
- CSMD3 | c.4195G>A p.E1399K (on ENST00000297405 / NM_001363185.1; = p.E1295K on NM_052900.3) | Missense Mutation (SNP) | VAF 15/74 reads (20%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.932); catalogued as COSV52164500, COSV52288099; called by muse, mutect2, varscan2
- CSMD3 | c.2611G>A p.E871K (on ENST00000297405 / NM_001363185.1; = p.E767K on NM_052900.3) | Missense Mutation (SNP) | VAF 24/91 reads (26%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.669); catalogued as rs753251128, COSV52327011; called by muse, mutect2, varscan2
- CSMD3 | c.550C>T p.P184S | Missense Mutation (SNP) | VAF 56/82 reads (68%) | SIFT deleterious (0.02); PolyPhen benign (0.254); catalogued as COSV52327027; called by muse, mutect2, varscan2
- CST6 | c.281G>A p.G94E | Missense Mutation (SNP) | VAF 18/53 reads (34%) | SIFT tolerated (1); PolyPhen benign (0.028); catalogued as COSV56413678; called by muse, mutect2, varscan2
- CSTL1 | c.25C>T p.P9S | Missense Mutation (SNP) | VAF 29/61 reads (48%) | SIFT tolerated (0.32); PolyPhen benign (0.005); catalogued as COSV55677888; called by muse, mutect2, varscan2
- CTAGE6 | c.1237G>A p.E413K | Missense Mutation (SNP) | VAF 23/193 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.044); catalogued as COSV69919008; called by muse, varscan2
- CTAGE6 | c.1216G>A p.E406K | Missense Mutation (SNP) | VAF 20/127 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs778979165, COSV69919016; called by muse, varscan2
- CTCFL | c.140T>G p.L47W | Missense Mutation (SNP) | VAF 98/398 reads (25%) | SIFT deleterious (0.05); PolyPhen benign (0.007); catalogued as COSV54779266; called by muse, mutect2, varscan2
- CTNNA2 | c.452C>T p.S151F | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT deleterious (0.04); PolyPhen benign (0.015); catalogued as COSV63603973; called by muse, mutect2, varscan2
- CTNNA2 | c.1675G>A p.E559K | Missense Mutation (SNP) | VAF 48/76 reads (63%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.689); catalogued as COSV58182888; called by muse, mutect2, varscan2
- CTNNA3 | c.883G>A p.E295K | Missense Mutation (SNP) | VAF 24/59 reads (41%) | SIFT tolerated (0.68); PolyPhen benign (0.001); catalogued as COSV101044302, COSV65559590; called by muse, mutect2, varscan2
- CTNNA3 | c.217G>A p.G73R | Missense Mutation (SNP) | VAF 24/61 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs752125801, COSV57718674, COSV57721676; called by muse, mutect2, varscan2
- CTNND2 | c.3502G>A p.D1168N | Missense Mutation (SNP) | VAF 64/91 reads (70%) | SIFT deleterious (0.01); PolyPhen benign (0.165); catalogued as rs756966820, COSV58908222; called by muse, mutect2, varscan2
- CTNND2 | c.1264C>T p.P422S | Missense Mutation (SNP) | VAF 61/100 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1192123931, COSV58889010, COSV58927064; called by muse, mutect2, varscan2
- CTRB2 | c.789C>A p.N263K | Missense Mutation (SNP) | VAF 36/44 reads (82%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.558); catalogued as rs34824152, COSV57316248; called by muse, mutect2, varscan2
- CUX2 | c.3998C>T p.P1333L | Missense Mutation (SNP) | VAF 48/138 reads (35%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0); catalogued as COSV55648761; called by muse, mutect2
- CWF19L2 | c.2317C>T p.L773F | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.892); catalogued as COSV56520693; called by muse, mutect2, varscan2
- CWH43 | c.772C>T p.R258C | Missense Mutation (SNP) | VAF 88/122 reads (72%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs762343467, COSV56936664, COSV56939862; called by muse, mutect2, varscan2
- CYFIP1 | c.3031G>A p.E1011K | Missense Mutation (SNP) | VAF 44/82 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs764318239, COSV57412341; called by muse, mutect2, varscan2
- CYLC1 | c.376C>T p.P126S | Missense Mutation (SNP) | VAF 5/8 reads (63%) | SIFT tolerated (0.45); PolyPhen benign (0.015); catalogued as COSV61416142; called by muse, mutect2
- CYLC2 | c.410G>A p.G137E | Missense Mutation (SNP) | VAF 5/10 reads (50%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV66336729, COSV66339490; called by muse, mutect2, varscan2
- CYP2A13 | c.781C>T p.P261S | Missense Mutation (SNP) | VAF 33/88 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.318); catalogued as COSV57840266; called by muse, mutect2, varscan2
- CYP2C19 | c.658C>T p.P220S | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT tolerated (0.19); PolyPhen benign (0.11); catalogued as rs867067400, COSV64907708; called by muse, mutect2, varscan2
- CYP2C8 | c.481+1G>A p.X161_splice | Splice Site (SNP) | VAF 38/164 reads (23%) | catalogued as rs772754152, COSV64875971, COSV64879031; called by muse, mutect2
- CYP2C9 | c.497C>T p.P166L | Missense Mutation (SNP) | VAF 16/90 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.93); catalogued as rs760085149, COSV53246320, COSV53253027; called by muse, varscan2
- CYP2S1 | c.661G>A p.E221K | Missense Mutation (SNP) | VAF 24/137 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.921); catalogued as rs778305839, COSV59506422; called by muse, mutect2, varscan2
- CYP3A4 | c.14C>T p.P5L | Missense Mutation (SNP) | VAF 22/109 reads (20%) | SIFT tolerated (0.1); PolyPhen benign (0.191); catalogued as COSV100315960; called by muse, mutect2, varscan2
- CYP4F11 | c.631G>A p.E211K | Missense Mutation (SNP) | VAF 24/94 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.102); catalogued as COSV56129710; called by muse, mutect2, varscan2
- CYP4F2 | c.1196C>T p.S399F | Missense Mutation (SNP) | VAF 63/124 reads (51%) | SIFT deleterious (0.05); PolyPhen benign (0.114); catalogued as COSV55621045; called by muse, mutect2, varscan2
- CYP4X1 | c.1260G>A p.W420* | Nonsense Mutation (SNP) | VAF 43/88 reads (49%) | catalogued as COSV64150455; called by muse, mutect2, varscan2
- DAB1 | c.1329G>A p.M443I (on ENST00000371231; = p.M410I on NM_021080.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 35/38 reads (92%) | SIFT tolerated (0.46); PolyPhen benign (0.003); catalogued as rs766791551, COSV64698451; called by muse, mutect2, varscan2
- DAW1 | c.756G>A p.R252= | Splice Region (SNP) | VAF 16/39 reads (41%) | catalogued as COSV100006329; called by muse, mutect2, varscan2
- DBH | c.1730G>A p.W577* | Nonsense Mutation (SNP) | VAF 17/69 reads (25%) | catalogued as rs77724989, COSV67549991; called by muse, mutect2, varscan2
- DBX1 | c.1000G>A p.G334S | Missense Mutation (SNP) | VAF 62/251 reads (25%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.062); catalogued as rs760316064, COSV57055349; called by muse, mutect2, varscan2
- DCAF8L1 | c.1780C>T p.R594* | Nonsense Mutation (SNP) | VAF 14/27 reads (52%) | catalogued as rs201455864, COSV71595237; called by muse, mutect2, varscan2
- DCC | c.208C>T p.P70S | Missense Mutation (SNP) | VAF 16/34 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV59101712; called by muse, mutect2, varscan2
- DCC | c.1451C>T p.S484F | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.044); catalogued as COSV59124064; called by muse, mutect2, varscan2
- DCDC1 | c.5201G>A p.G1734E (on ENST00000597505 / NM_001367979.1; = p.G841E on NM_020869.3) | Missense Mutation (SNP) | VAF 13/63 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.833); catalogued as COSV58003794, COSV58004156; called by muse, mutect2, varscan2
- DCDC2B | c.284G>A p.G95E | Missense Mutation (SNP) | VAF 12/16 reads (75%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs892898819, COSV52211433; called by muse, mutect2, varscan2
- DCP1A | c.767C>T p.S256L | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT tolerated (0.74); PolyPhen benign (0.011); catalogued as COSV99588254; called by mutect2, varscan2
- DCTN4 | c.479T>C p.V160A | Missense Mutation (SNP) | VAF 27/56 reads (48%) | SIFT tolerated (0.37); PolyPhen benign (0.007); catalogued as COSV69783122; called by muse, mutect2, varscan2
- DDHD1 | c.1520A>G p.N507S (on ENST00000323669; = p.N704S on NM_030637.3) | Missense Mutation (SNP) | VAF 33/155 reads (21%) | SIFT tolerated (0.41); PolyPhen benign (0.005); catalogued as rs770954231, COSV60362917; called by muse, mutect2, varscan2
- DDX4 | c.1759C>T p.R587C | Missense Mutation (SNP) | VAF 45/77 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61754856; called by muse, mutect2, varscan2
- DDX47 | c.736C>T p.P246S | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.983); catalogued as COSV61912128; called by muse, mutect2, varscan2
- DDX5 | c.881T>G p.L294R | Missense Mutation (SNP) | VAF 52/132 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV56751493; called by muse, mutect2
- DDX60 | c.2491C>T p.R831C | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.964); catalogued as rs778806064, COSV67095443; called by muse, mutect2, varscan2
- DDX60 | c.287A>T p.N96I | Missense Mutation (SNP) | VAF 28/67 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.352); catalogued as COSV67099441; called by muse, mutect2, varscan2
- DDX60L | c.3895G>A p.D1299N | Missense Mutation (SNP) | VAF 10/16 reads (63%) | SIFT tolerated (0.11); PolyPhen benign (0.22); catalogued as COSV52722453; called by muse, mutect2, varscan2
- DEDD2 | c.566C>T p.S189F | Missense Mutation (SNP) | VAF 39/107 reads (36%) | SIFT tolerated (0.15); PolyPhen benign (0.011); catalogued as rs757943173, COSV60143047; called by muse, mutect2, varscan2
- DEFB105A | c.95C>T p.S32F | Missense Mutation (SNP) | VAF 13/77 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.189); catalogued as COSV58294716; called by mutect2, varscan2
- DEFB110 | c.119G>A p.G40D | Missense Mutation (SNP) | VAF 18/97 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV64485008; called by muse, mutect2, varscan2
- DENND2A | c.523G>A p.A175T | Missense Mutation (SNP) | VAF 25/56 reads (45%) | SIFT tolerated (0.12); PolyPhen benign (0.067); catalogued as COSV52052264, COSV52059526; called by muse, mutect2, varscan2
- DENND5B | c.3046G>A p.E1016K | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV100172283; called by muse, mutect2, varscan2
- DEUP1 | c.376C>T p.P126S | Missense Mutation (SNP) | VAF 17/24 reads (71%) | SIFT tolerated (0.41); PolyPhen benign (0.003); catalogued as COSV53217023; called by muse, mutect2, varscan2
- DGAT2L6 | c.237G>A p.W79* | Nonsense Mutation (SNP) | VAF 12/20 reads (60%) | catalogued as COSV60718847; called by muse, mutect2, varscan2
- DGKB | c.13G>A p.E5K | Missense Mutation (SNP) | VAF 37/51 reads (73%) | SIFT tolerated (0.58); PolyPhen possibly damaging (0.827); catalogued as COSV51779744; called by muse, mutect2, varscan2
- DGKD | c.881C>T p.S294L (on ENST00000264057 / NM_152879.3; = p.S250L on NM_003648.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.079); catalogued as rs1408799133, COSV51109078; called by muse, mutect2, varscan2
- DGKG | c.2098C>T p.L700F | Missense Mutation (SNP) | VAF 19/78 reads (24%) | SIFT tolerated (0.16); PolyPhen benign (0.082); catalogued as COSV53973315; called by muse, mutect2, varscan2
- DGKH | c.1714C>T p.P572S | Missense Mutation (SNP) | VAF 41/60 reads (68%) | SIFT tolerated (0.26); PolyPhen benign (0.045); catalogued as COSV54942216; called by muse, mutect2, varscan2
- DGKH | c.3340C>T p.P1114S | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT tolerated (0.97); PolyPhen benign (0.005); catalogued as COSV54942241; called by muse, mutect2, varscan2
- DGKK | c.3154G>A p.E1052K | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.787); catalogued as COSV65709493; called by muse, mutect2, varscan2
- DGKK | c.1999G>A p.E667K | Missense Mutation (SNP) | VAF 11/12 reads (92%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.714); catalogued as COSV65706386; called by muse, mutect2
- DGLUCY | c.1564G>A p.G522R | Missense Mutation (SNP) | VAF 44/107 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.872); catalogued as COSV56370461; called by muse, mutect2, varscan2
- DHRS9 | c.158G>A p.G53E | Missense Mutation (SNP) | VAF 22/61 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59141774; called by muse, mutect2, varscan2
- DHX30 | c.1337C>T p.A446V (on ENST00000445061 / NM_138615.3; = p.A407V on NM_014966.3) | Missense Mutation (SNP) | VAF 33/94 reads (35%) | SIFT tolerated (0.2); PolyPhen benign (0.295); catalogued as COSV99276421; called by muse, mutect2, varscan2
- DICER1 | c.4649C>T p.T1550I | Missense Mutation (SNP) | VAF 21/94 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58628706; called by muse, mutect2, varscan2
- DIDO1 | c.5549G>A p.G1850E | Missense Mutation (SNP) | VAF 75/163 reads (46%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.505); catalogued as COSV56615072, COSV99827281; called by muse, mutect2, varscan2
- DIDO1 | c.4148G>A p.R1383K | Missense Mutation (SNP) | VAF 38/198 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV56631668; called by muse, mutect2, varscan2
- DIDO1 | c.185G>A p.R62Q | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV99827287; called by muse, mutect2
- DIPK2A | c.664C>T p.P222S | Missense Mutation (SNP) | VAF 31/90 reads (34%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.986); catalogued as COSV59858494; called by muse, mutect2, varscan2
- DISP2 | c.2975C>T p.S992F | Missense Mutation (SNP) | VAF 24/86 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.329); catalogued as COSV99139875; called by muse, mutect2, varscan2
- DKK3 | c.314G>A p.G105E | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT deleterious (0.05); PolyPhen benign (0.142); catalogued as COSV58867834, COSV58868276; called by muse, mutect2, varscan2
- DLG2 | c.904G>A p.E302K | Missense Mutation (SNP) | VAF 40/85 reads (47%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as COSV54676338; called by muse, mutect2, varscan2
- DLGAP1 | c.1871C>T p.T624I | Missense Mutation (SNP) | VAF 15/29 reads (52%) | SIFT tolerated (0.08); PolyPhen benign (0.014); catalogued as COSV59837700; called by muse, mutect2, varscan2
- DLGAP2 | c.1001C>T p.P334L | Missense Mutation (SNP) | VAF 22/125 reads (18%) | SIFT tolerated (0.66); PolyPhen probably damaging (0.998); catalogued as rs1404079466, COSV70098229; called by muse, mutect2, varscan2
- DLGAP4 | c.1232A>G p.N411S | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as COSV59417897, COSV59423748; called by muse, mutect2, varscan2
- DMBT1 | c.104C>T p.P35L | Missense Mutation (SNP) | VAF 19/112 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.015); catalogued as COSV57563553; called by muse, mutect2, varscan2
- DMBT1 | c.5404G>A p.D1802N (on ENST00000338354 / NM_001377530.1; = p.D1045N on NM_004406.3) | Missense Mutation (SNP) | VAF 129/320 reads (40%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as COSV57563581; called by muse, mutect2, varscan2
- DMD | c.5101C>T p.L1701F | Missense Mutation (SNP) | VAF 24/57 reads (42%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.666); catalogued as COSV63793994; called by muse, mutect2, varscan2
- DNA2 | c.1993C>T p.L665F | Missense Mutation (SNP) | VAF 7/9 reads (78%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs369989395, COSV64430346; called by muse, mutect2, varscan2
- DNAH1 | c.11558G>A p.C3853Y | Missense Mutation (SNP) | VAF 46/204 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV56241046; called by muse, mutect2, varscan2
- DNAH10 | c.4280C>T p.T1427I (on ENST00000409039; = p.T1366I on NM_207437.3) | Missense Mutation (SNP) | VAF 22/53 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV101292844; called by muse, mutect2, varscan2
- DNAH10 | c.4757C>T p.P1586L (on ENST00000409039; = p.P1525L on NM_207437.3) | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.709); catalogued as COSV69002535; called by muse, mutect2, varscan2
- DNAH10 | c.11698G>A p.D3900N (on ENST00000409039; = p.D3839N on NM_207437.3) | Missense Mutation (SNP) | VAF 29/61 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV69002557; called by muse, mutect2, varscan2
- DNAH11 | c.1727G>A p.G576E | Missense Mutation (SNP) | VAF 34/68 reads (50%) | SIFT tolerated (0.14); PolyPhen probably damaging (1); catalogued as COSV60982845; called by muse, mutect2, varscan2
- DNAH11 | c.5158G>A p.E1720K | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.154); catalogued as rs1215432927, COSV60969973, COSV60982873; called by muse, mutect2, varscan2
- DNAH11 | c.9394C>T p.H3132Y | Missense Mutation (SNP) | VAF 48/72 reads (67%) | SIFT deleterious (0); PolyPhen benign (0.138); catalogued as COSV60974937; called by muse, mutect2, varscan2
- DNAH11 | c.11933A>T p.K3978I | Missense Mutation (SNP) | VAF 35/114 reads (31%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.771); catalogued as COSV60982915; called by muse, mutect2, varscan2
- DNAH17 | c.3059G>A p.W1020* | Nonsense Mutation (SNP) | VAF 6/22 reads (27%) | catalogued as rs1400803669, COSV67761419; called by muse, mutect2, varscan2
- DNAH3 | c.11272G>A p.E3758K | Missense Mutation (SNP) | VAF 26/47 reads (55%) | SIFT tolerated (0.09); PolyPhen benign (0.257); catalogued as rs868191973, COSV54510062; called by muse, mutect2, varscan2
- DNAH3 | c.4223C>T p.T1408I | Missense Mutation (SNP) | VAF 48/85 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54515170; called by muse, mutect2, varscan2
- DNAH5 | c.9865C>T p.P3289S | Missense Mutation (SNP) | VAF 122/174 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54253698; called by muse, varscan2
- DNAH5 | c.9617G>A p.G3206E | Missense Mutation (SNP) | VAF 70/98 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54209483, COSV99447926; called by muse, varscan2
- DNAH5 | c.7132G>A p.E2378K | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as rs1409796457, COSV54225388, COSV54253741; called by muse, mutect2, varscan2
- DNAH5 | c.4473G>A p.M1491I | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.402); catalogued as COSV54208385; called by muse, mutect2, varscan2
- DNAH5 | c.4367T>C p.L1456P | Missense Mutation (SNP) | VAF 31/50 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54253763; called by muse, mutect2
- DNAH5 | c.3266C>T p.T1089I | Missense Mutation (SNP) | VAF 16/70 reads (23%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as COSV54253775; called by muse, mutect2, varscan2
- DNAH5 | c.643G>A p.E215K | Missense Mutation (SNP) | VAF 40/54 reads (74%) | SIFT tolerated (0.81); PolyPhen benign (0); catalogued as COSV54253788; called by muse, mutect2, varscan2
- DNAH7 | c.10416G>A p.M3472I | Missense Mutation (SNP) | VAF 17/25 reads (68%) | SIFT tolerated (0.15); PolyPhen benign (0.034); catalogued as COSV56753213; called by muse, mutect2, varscan2
- DNAH7 | c.6838G>A p.D2280N | Missense Mutation (SNP) | VAF 26/103 reads (25%) | SIFT tolerated (0.39); PolyPhen benign (0.003); catalogued as COSV100417553, COSV56787919; called by muse, varscan2
- DNAH7 | c.4858C>T p.R1620C | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs142469040, COSV56787927; called by muse, mutect2, varscan2
- DNAH7 | c.3167G>A p.G1056E | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs765912339, COSV56787937; called by muse, mutect2, varscan2
- DNAH8 | c.6295G>A p.E2099K | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT tolerated (0.32); PolyPhen benign (0.039); catalogued as COSV59482220; called by muse, mutect2
- DNAH8 | c.9866C>T p.P3289L | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100547301, COSV59482246; called by muse, mutect2
- DNAH8 | c.11497G>A p.G3833R | Missense Mutation (SNP) | VAF 27/188 reads (14%) | SIFT tolerated (0.51); PolyPhen benign (0.296); catalogued as COSV59482274; called by muse, mutect2, varscan2
- DNAH9 | c.2596G>A p.E866K | Missense Mutation (SNP) | VAF 18/45 reads (40%) | SIFT deleterious (0.05); PolyPhen benign (0.103); catalogued as rs1443985595, COSV52335653; called by muse, mutect2, varscan2
- DNAH9 | c.6295C>T p.P2099S | Missense Mutation (SNP) | VAF 48/66 reads (73%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs149674795; called by muse, varscan2
- DNAH9 | c.8641C>T p.L2881F | Missense Mutation (SNP) | VAF 18/100 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as COSV52377991; called by muse, varscan2
- DNAH9 | c.8692G>A p.D2898N | Missense Mutation (SNP) | VAF 16/90 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV52332075; called by muse, varscan2
- DNAH9 | c.12130G>A p.E4044K | Missense Mutation (SNP) | VAF 76/361 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV52378033, COSV99307532; called by muse, mutect2, varscan2
- DNAI4 | c.1297G>A p.E433K | Missense Mutation (SNP) | VAF 35/37 reads (95%) | SIFT tolerated (0.19); PolyPhen benign (0.033); catalogued as COSV64023959; called by muse, mutect2, varscan2
- DNAJC13 | c.2509G>A p.E837K | Missense Mutation (SNP) | VAF 44/150 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.572); catalogued as rs756700114, COSV53458643; called by muse, mutect2
- DNAJC13 | c.3298G>A p.E1100K | Missense Mutation (SNP) | VAF 17/57 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.664); catalogued as COSV53458664; called by muse, mutect2, varscan2
- DNMBP | c.4433C>T p.S1478F | Missense Mutation (SNP) | VAF 62/91 reads (68%) | SIFT deleterious (0.03); PolyPhen benign (0.293); catalogued as COSV60633504; called by muse, mutect2, varscan2
- DNMT3B | c.2533C>T p.P845S | Missense Mutation (SNP) | VAF 39/116 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV52423887; called by muse, mutect2, varscan2
- DOCK3 | c.5429G>A p.R1810Q | Missense Mutation (SNP) | VAF 32/114 reads (28%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.342); catalogued as rs746225932, COSV56528543; called by muse, mutect2, varscan2
- DOCK5 | c.256C>T p.P86S | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.163); catalogued as rs1357869669, COSV52411925; called by muse, mutect2, varscan2
- DOP1B | c.578C>T p.P193L | Missense Mutation (SNP) | VAF 18/74 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs778871181, COSV101215311, COSV67696312; called by muse, mutect2, varscan2
- DPH7 | c.1020G>A p.W340* | Nonsense Mutation (SNP) | VAF 20/51 reads (39%) | catalogued as COSV53024040; called by muse, mutect2, varscan2
- DPP6 | c.673C>T p.P225S (on ENST00000377770 / NM_001364500.2; = p.P163S on NM_001936.5) | Missense Mutation (SNP) | VAF 3/11 reads (27%) | SIFT tolerated (0.73); PolyPhen benign (0.162); catalogued as COSV59646911; called by muse, mutect2
- DPPA2 | c.440C>T p.S147L | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.491); catalogued as rs768502278, COSV72118048; called by muse, mutect2, varscan2
- DPYD | c.863C>T p.P288L | Missense Mutation (SNP) | VAF 16/35 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.677); catalogued as COSV64615652; called by muse, mutect2, varscan2
- DQX1 | c.824C>T p.S275F | Missense Mutation (SNP) | VAF 29/99 reads (29%) | SIFT tolerated (0.11); PolyPhen benign (0.034); catalogued as COSV66353687; called by muse, mutect2, varscan2
- DSC1 | c.448C>T p.P150S | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57151954; called by muse, mutect2, varscan2
- DSC2 | c.1810C>T p.H604Y | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as COSV51864942; called by muse, mutect2
- DSC3 | c.523G>A p.G175R | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100844338; called by muse, mutect2, varscan2
- DSCAM | c.5992C>T p.H1998Y | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.954); catalogued as COSV101261625; called by muse, mutect2, varscan2
- DSCAM | c.796G>A p.E266K | Missense Mutation (SNP) | VAF 26/57 reads (46%) | SIFT tolerated (0.36); PolyPhen probably damaging (0.95); catalogued as rs770432921, COSV68030480; called by muse, mutect2, varscan2
- DSCAM | c.122G>A p.G41E | Missense Mutation (SNP) | VAF 36/171 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.306); catalogued as rs1360887980, COSV68655329; called by muse, mutect2, varscan2
- DSCAML1 | c.6240G>A p.M2080I (on ENST00000321322; = p.M2020I on NM_020693.4) | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0); catalogued as COSV100356840, COSV58403259; called by muse, mutect2, varscan2
- DSEL | c.1156C>T p.P386S | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT tolerated (0.27); PolyPhen benign (0.423); catalogued as rs865996027, COSV59494950; called by muse, mutect2, varscan2
- DSG1 | c.1774G>A p.G592R | Missense Mutation (SNP) | VAF 43/70 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as COSV57135123; called by muse, mutect2, varscan2
- DSG1 | c.2368G>A p.E790K | Missense Mutation (SNP) | VAF 27/100 reads (27%) | SIFT tolerated (0.19); PolyPhen benign (0.142); catalogued as COSV57136459; called by muse, mutect2, varscan2
- DSG1 | c.2737C>T p.H913Y | Missense Mutation (SNP) | VAF 72/126 reads (57%) | SIFT deleterious (0); PolyPhen benign (0.091); catalogued as COSV57133516; called by muse, mutect2, varscan2
- DSG4 | c.1625G>A p.R542K | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT tolerated (0.34); PolyPhen benign (0.001); catalogued as COSV57389920, COSV57397981; called by muse, mutect2
- DSP | c.4954G>A p.E1652K | Missense Mutation (SNP) | VAF 28/171 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.141); catalogued as rs267601119, COSV65791352; called by muse, mutect2, varscan2
- DST | c.9038A>T p.N3013I | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.181); catalogued as COSV99760354; called by muse, mutect2, varscan2
- DTNA | c.2102C>T p.P701L | Missense Mutation (SNP) | VAF 32/42 reads (76%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.159); catalogued as rs1210998193, COSV52027062, COSV99314409; called by muse, mutect2, varscan2
- DUOX2 | c.3251G>A p.R1084Q | Missense Mutation (SNP) | VAF 18/70 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs558919433, CM164602, COSV66532259; called by muse, mutect2, varscan2
- DUOX2 | c.1187C>T p.S396F | Missense Mutation (SNP) | VAF 15/178 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as rs1315366889, COSV59909715; called by muse, mutect2
- DUXA | c.454C>T p.R152* | Nonsense Mutation (SNP) | VAF 8/52 reads (15%) | catalogued as rs773479524, COSV101617164, COSV73729528; called by muse, varscan2
- DUXA | c.439-1G>A p.X147_splice | Splice Site (SNP) | VAF 8/40 reads (20%) | catalogued as COSV73729636, COSV73729899; called by muse, varscan2
- DYNLRB2 | c.172C>T p.R58C | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as rs751931828, COSV58416178; called by muse, mutect2, varscan2
- DYRK3 | c.953C>T p.S318F | Missense Mutation (SNP) | VAF 19/126 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65608105; called by muse, mutect2, varscan2
- E2F1 | c.880G>A p.D294N | Missense Mutation (SNP) | VAF 12/62 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.18); catalogued as rs762296081, COSV55777414; called by muse, mutect2, varscan2
- ECM1 | c.875C>T p.S292F | Missense Mutation (SNP) | VAF 48/98 reads (49%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV60875349; called by muse, mutect2, varscan2
- EDN1 | c.546G>A p.M182I | Missense Mutation (SNP) | VAF 30/201 reads (15%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV65080791; called by muse, mutect2, varscan2
- EDN2 | c.250C>T p.P84S | Missense Mutation (SNP) | VAF 41/45 reads (91%) | SIFT deleterious (0); PolyPhen benign (0.432); catalogued as rs768322245, COSV65423692; called by muse, varscan2
- EEA1 | c.3508C>T p.Q1170* | Nonsense Mutation (SNP) | VAF 25/28 reads (89%) | catalogued as COSV59290094; called by muse, mutect2, varscan2
- EEF1AKMT4-ECE2 | c.413C>T p.A138V | Missense Mutation (SNP) | VAF 22/73 reads (30%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as COSV56182451; called by muse, mutect2, varscan2
- EEF1AKMT4-ECE2 | c.2213A>G p.N738S | Missense Mutation (SNP) | VAF 33/129 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62571102; called by muse, mutect2, varscan2
- EFHC1 | c.1261C>T p.R421C | Missense Mutation (SNP) | VAF 25/126 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.779); catalogued as rs144389178; called by muse, mutect2, varscan2
- EFHC2 | c.1679C>A p.S560Y | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT tolerated (0.11); PolyPhen benign (0.007); catalogued as COSV59094581; called by muse, mutect2, varscan2
- EFL1 | c.965C>T p.S322F | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as COSV51610227; called by muse, mutect2, varscan2
- EFNA5 | c.367C>T p.P123S | Missense Mutation (SNP) | VAF 23/36 reads (64%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV60958243; called by muse, mutect2, varscan2
- EGF | c.968G>A p.G323E | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT tolerated (0.41); PolyPhen benign (0.025); catalogued as COSV99491407; called by muse, varscan2
- EGFL6 | c.1166C>T p.S389F | Missense Mutation (SNP) | VAF 33/36 reads (92%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.77); catalogued as rs761849411, COSV63635459; called by muse, mutect2, varscan2
- EGFR | c.1766C>T p.P589L | Missense Mutation (SNP) | VAF 42/109 reads (39%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.488); catalogued as rs751570775, COSV51799159; called by muse, mutect2, varscan2
- EHD3 | c.673G>A p.E225K | Missense Mutation (SNP) | VAF 29/100 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.006); catalogued as rs765669139, COSV59033167; called by muse, mutect2, varscan2
- EHHADH | c.1907G>A p.G636E | Missense Mutation (SNP) | VAF 19/100 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV51633668; called by muse, mutect2, varscan2
- EIF3B | c.1601C>T p.P534L | Missense Mutation (SNP) | VAF 56/147 reads (38%) | SIFT tolerated (0.2); PolyPhen benign (0.058); catalogued as rs747838544, COSV62805126; called by muse, mutect2, varscan2
- EIF4H | c.610G>C p.E204Q | Missense Mutation (SNP) | VAF 12/86 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.932); catalogued as COSV56083629; called by muse, mutect2, varscan2
- ELAVL2 | c.505G>A p.G169R | Missense Mutation (SNP) | VAF 20/68 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56358068, COSV56371535; called by muse, varscan2
- ELMOD1 | c.302C>T p.S101F | Missense Mutation (SNP) | VAF 25/70 reads (36%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.612); catalogued as COSV56196942; called by muse, mutect2, varscan2
- ELMOD1 | c.505C>T p.P169S | Missense Mutation (SNP) | VAF 15/25 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56196951; called by muse, mutect2, varscan2
- ELN | c.466C>T p.P156S | Missense Mutation (SNP) | VAF 20/48 reads (42%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.776); catalogued as COSV52716075; called by muse, mutect2, varscan2
- ELOA2 | c.787C>T p.P263S | Missense Mutation (SNP) | VAF 24/62 reads (39%) | SIFT tolerated (0.16); PolyPhen benign (0.001); catalogued as COSV99798441; called by muse, mutect2
- EML1 | c.1889C>T p.S630F | Missense Mutation (SNP) | VAF 52/114 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV51753230; called by muse, mutect2, varscan2
- ENAM | c.2134G>A p.E712K | Missense Mutation (SNP) | VAF 25/71 reads (35%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.584); catalogued as COSV68537068; called by muse, mutect2, varscan2
- ENAM | c.2818G>A p.E940K | Missense Mutation (SNP) | VAF 63/108 reads (58%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); catalogued as rs371648352; called by muse, mutect2, varscan2
- ENDOD1 | c.682C>T p.P228S | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.985); catalogued as COSV53591399; called by muse, mutect2, varscan2
- ENKUR | c.487G>A p.E163K | Missense Mutation (SNP) | VAF 16/84 reads (19%) | SIFT tolerated (0.09); PolyPhen benign (0.049); catalogued as rs369720464; called by muse, mutect2, varscan2
- ENPEP | c.1202G>A p.G401E | Missense Mutation (SNP) | VAF 12/62 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54457579; called by muse, mutect2, varscan2
- ENPP1 | c.328G>A p.G110S | Missense Mutation (SNP) | VAF 25/46 reads (54%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.826); catalogued as rs372420217; called by muse, mutect2, varscan2
- ENPP5 | c.562G>A p.E188K | Missense Mutation (SNP) | VAF 35/84 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as COSV57910070; called by muse, mutect2, varscan2
- ENPP7 | c.181G>A p.G61R | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.907); catalogued as rs551732034; called by muse, mutect2, varscan2
- ENTPD1 | c.448G>A p.D150N | Missense Mutation (SNP) | VAF 40/147 reads (27%) | SIFT tolerated (0.37); PolyPhen benign (0.003); catalogued as COSV64600424; called by muse, mutect2, varscan2
- ENTPD2 | c.721C>T p.L241F | Missense Mutation (SNP) | VAF 23/27 reads (85%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1399915171, COSV57076677; called by muse, mutect2, varscan2
- ENTPD3 | c.598-2A>T p.X200_splice | Splice Site (SNP) | VAF 22/33 reads (67%) | catalogued as COSV57196498; called by muse, mutect2, varscan2
- ENTPD6 | c.370C>T p.P124S | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT tolerated (0.32); PolyPhen benign (0.133); catalogued as COSV61752494; called by muse, mutect2, varscan2
- EP300 | c.6160C>T p.L2054F | Missense Mutation (SNP) | VAF 31/112 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54346234; called by muse, mutect2, varscan2
- EPAS1 | c.164C>T p.S55F | Missense Mutation (SNP) | VAF 90/190 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); catalogued as COSV55387648; called by muse, mutect2, varscan2
- EPB41L2 | c.199G>A p.E67K | Missense Mutation (SNP) | VAF 30/66 reads (45%) | SIFT tolerated (0.09); PolyPhen benign (0.05); catalogued as COSV61359261; called by muse, mutect2, varscan2
- EPB41L4A | c.855G>A p.W285* | Nonsense Mutation (SNP) | VAF 21/52 reads (40%) | catalogued as COSV54881370; called by muse, mutect2, varscan2
- EPB41L4B | c.1369C>T p.P457S | Missense Mutation (SNP) | VAF 33/44 reads (75%) | SIFT tolerated (0.14); PolyPhen benign (0.147); catalogued as rs745392405, COSV65798897; called by muse, mutect2, varscan2
- EPB42 | c.1808C>T p.P603L (on ENST00000441366 / NM_001114134.2; = p.P633L on NM_000119.3) | Missense Mutation (SNP) | VAF 21/84 reads (25%) | SIFT tolerated (0.07); PolyPhen benign (0.194); catalogued as rs773924102, COSV55751827; called by muse, mutect2, varscan2
- EPHA1 | c.991G>A p.G331S | Missense Mutation (SNP) | VAF 19/69 reads (28%) | SIFT deleterious (0.05); PolyPhen benign (0.024); catalogued as COSV51976747; called by muse, mutect2, varscan2
- EPHA4 | c.1196C>T p.S399F | Missense Mutation (SNP) | VAF 62/183 reads (34%) | SIFT tolerated (0.5); PolyPhen possibly damaging (0.717); catalogued as rs868224085, COSV56043572; called by muse, varscan2
- EPHA4 | c.1082C>T p.S361F | Missense Mutation (SNP) | VAF 53/122 reads (43%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.588); catalogued as COSV56029452; called by muse, varscan2
- EPHA6 | c.1174C>T p.P392S | Missense Mutation (SNP) | VAF 61/96 reads (64%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.998); catalogued as COSV101061848, COSV101065804, COSV67575419; called by muse, mutect2, varscan2
- EPHA6 | c.1540G>A p.G514R | Missense Mutation (SNP) | VAF 29/101 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67568038; called by muse, mutect2, varscan2
- EPHA7 | c.1807C>T p.P603S | Missense Mutation (SNP) | VAF 24/47 reads (51%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); catalogued as rs868510824, COSV65177406, COSV65194672; called by muse, mutect2, varscan2
- EPHA7 | c.620C>T p.S207F | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT tolerated (0.72); PolyPhen possibly damaging (0.694); catalogued as COSV65170607; called by muse, mutect2, varscan2
- EPHB1 | c.1769G>A p.G590E | Missense Mutation (SNP) | VAF 56/188 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.162); catalogued as COSV67662871, COSV67669274; called by muse, varscan2
- EPHX2 | c.1250T>C p.L417S | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0.181); catalogued as COSV66846160; called by muse, mutect2, varscan2
- EPS8 | c.862C>T p.Q288* | Nonsense Mutation (SNP) | VAF 18/65 reads (28%) | catalogued as COSV99843743; called by muse, mutect2, varscan2
- ERBB4 | c.2441A>C p.N814T | Missense Mutation (SNP) | VAF 26/111 reads (23%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.995); catalogued as COSV61524480; called by muse, mutect2, varscan2
- ERBB4 | c.341G>A p.R114Q | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.987); catalogued as rs767277487, COSV53533522; called by muse, mutect2, varscan2
- ERCC2 | c.2101C>T p.L701F | Missense Mutation (SNP) | VAF 34/83 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.152); catalogued as COSV67270717; called by muse, mutect2, varscan2
- ERICH3 | c.4571C>T p.S1524F | Missense Mutation (SNP) | VAF 107/182 reads (59%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.549); catalogued as rs745496149, COSV58617827; called by muse, mutect2, varscan2
- ERMARD | c.1448C>G p.T483R | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT tolerated (0.08); PolyPhen benign (0.052); catalogued as COSV64647688, COSV64648912; called by muse, mutect2, varscan2
- ESPL1 | c.5896C>T p.R1966* | Nonsense Mutation (SNP) | VAF 24/124 reads (19%) | catalogued as rs1323144516, COSV54476569; called by muse, mutect2, varscan2
- ESR1 | c.1300C>T p.R434W | Missense Mutation (SNP) | VAF 15/26 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs777783665, COSV52792602; called by muse, mutect2, varscan2
- EXOC3 | c.611G>A p.R204H | Missense Mutation (SNP) | VAF 19/115 reads (17%) | SIFT tolerated (0.1); PolyPhen benign (0.133); catalogued as rs1021801165, COSV59268810; called by muse, mutect2, varscan2
- EXOC7 | c.2185C>T p.R729C (on ENST00000335146 / NM_001145297.4; = p.R647C on NM_015219.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 33/135 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs760890089, COSV58037064, COSV58037993; called by muse, mutect2, varscan2
- EXPH5 | c.3786A>T p.K1262N | Missense Mutation (SNP) | VAF 30/38 reads (79%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV56208686; called by muse, mutect2, varscan2
- EXT2 | c.1573C>T p.P525S (on ENST00000343631; = p.P558S on NM_000401.3) | Missense Mutation (SNP) | VAF 20/96 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59155514; called by muse, mutect2, varscan2
- EYA1 | c.580G>A p.G194R | Missense Mutation (SNP) | VAF 18/98 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58168948; called by muse, mutect2, varscan2
- EYA2 | c.1201T>C p.L401= | Splice Region (SNP) | VAF 4/20 reads (20%) | catalogued as COSV57951141; called by mutect2, varscan2
- EYS | c.154G>A p.D52N | Missense Mutation (SNP) | VAF 14/85 reads (16%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.001); catalogued as COSV60997666, COSV61000636; called by muse, mutect2, varscan2
- EZH1 | c.1729G>A p.A577T | Missense Mutation (SNP) | VAF 25/98 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); catalogued as COSV70549845, COSV70550836; called by muse, mutect2, varscan2
- F11 | c.1128G>A p.M376I | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT tolerated (0.49); PolyPhen benign (0.261); catalogued as rs763964150, COSV53009774; called by muse, mutect2
- F13B | c.98G>A p.G33E | Missense Mutation (SNP) | VAF 141/244 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66373340, COSV66374568; called by muse, mutect2, varscan2
- F2R | c.998T>A p.L333Q | Missense Mutation (SNP) | VAF 23/62 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV59930267; called by muse, mutect2, varscan2
3,837 further variants in this file (2,146 protein-altering or splice-affecting, 1,565 silent, 126 other) are not listed here.
